Somatic mutation profile of tumor specimen TCGA-44-3918-01B (aliquot TCGA-44-3918-01B-02D-A271-08) from TCGA case TCGA-44-3918, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 60.9 years (22,236 days).
Specimen TCGA-44-3918-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a7e655af-867c-4350-946c-9856fd1b4b22.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-3918-10A (Blood Derived Normal), aliquot TCGA-44-3918-10A-01D-A271-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/62dc818d-45a5-43c4-a29b-311fc55d6cf9

The open-access MAF lists 961 somatic variants for this specimen: 762 protein-altering or splice-affecting, 175 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 648, Silent 175, Nonsense Mutation 47, Splice Site 27, Frame Shift Del 24, Frame Shift Ins 9, RNA 8, Intron 8, Splice Region 5, 3'UTR 3, 5'UTR 3, 3'Flank 2.

Variants (750 of 961; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.2991G>T p.R997S | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs755501749, COSV62203559; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SCN5A | c.3718G>C p.E1240Q (on ENST00000333535 / NM_198056.3; = p.E1239Q on NM_000335.5) | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as rs199473211, CM024648; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.920-2A>G p.X307_splice | Splice Site (SNP) | VAF 19/57 reads (33%) | hotspot (GDC flag); catalogued as rs397516439, COSV52693974, COSV52706655, COSV52945558, COSV53066011; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.1820C>G p.T607S (on ENST00000272895 / NM_173076.3; = p.T289S on NM_015657.3) | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV55959662; called by muse, mutect2, varscan2
- ABCA13 | c.6778A>G p.I2260V | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as rs770312852, COSV70028933; called by muse, mutect2, varscan2
- ABCA7 | c.5521A>T p.T1841S | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.192); catalogued as COSV54029678; called by muse, mutect2, varscan2
- ABCB5 | c.854T>C p.I285T | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.106); catalogued as rs748373481, COSV99328771; called by muse, mutect2, varscan2
- ABCB7 | c.1807G>A p.G603R (on ENST00000373394 / NM_001271696.3; = p.G604R on NM_004299.6) | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99504497; called by muse, mutect2, varscan2
- ABCC4 | c.647G>T p.W216L | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV65312829; called by muse, mutect2, varscan2
- ABI3BP | c.1235C>A p.P412Q | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52536514; called by muse, mutect2, varscan2
- ABRACL | c.31G>C p.V11L | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.059); catalogued as COSV62771505; called by muse, mutect2, varscan2
- AC004593.2 | c.348G>C p.K116N | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.994); catalogued as COSV56092306; called by muse, mutect2
- AC136428.1 | c.329del p.T110Rfs*7 | Frame Shift Del (DEL) | VAF 48/266 reads (18%) | catalogued as COSV101434976; called by mutect2, varscan2
- ACAD10 | c.1322A>T p.E441V | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as COSV100564325; called by mutect2, varscan2
- ACSM2A | c.1710G>A p.M570I (on ENST00000219054; = p.M491I on NM_001308169.2) | Missense Mutation (SNP) | VAF 57/221 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs757378811, COSV54584726, COSV99525284; called by muse, mutect2, varscan2
- ACTL6A | c.112C>A p.P38T | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66998978; called by muse, mutect2
- ACTL9 | c.1117C>A p.Q373K | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.95); PolyPhen possibly damaging (0.557); catalogued as COSV100185414; called by muse, mutect2
- ACVR2A | c.1285C>T p.Q429* | Nonsense Mutation (SNP) | VAF 30/124 reads (24%) | catalogued as COSV54022625; called by muse, mutect2, varscan2
- ADAMTS12 | c.2267G>T p.G756V | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV61263232, COSV61272776; called by muse, mutect2, varscan2
- ADAMTS3 | c.499G>A p.G167S | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99711400; called by muse, mutect2, varscan2
- ADAMTS4 | c.1090+2T>A p.X364_splice | Splice Site (SNP) | VAF 54/172 reads (31%) | catalogued as COSV63487845; called by muse, mutect2, varscan2
- ADAMTS6 | c.2705A>T p.E902V | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.206); catalogued as COSV100068460, COSV58682898; called by muse, mutect2
- ADAMTS7 | c.4282G>T p.G1428C | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101183136; called by muse, mutect2, varscan2
- ADAMTSL1 | c.806G>C p.G269A | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV52815817, COSV52820281; called by muse, mutect2
- ADAMTSL3 | c.1469G>T p.C490F | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54448184, COSV54465044; called by muse, mutect2
- ADCY8 | c.2017C>A p.H673N | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.579); catalogued as COSV53908148; called by muse, mutect2, varscan2
- AIM2 | c.607C>A p.P203T | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as COSV63699769; called by muse, varscan2
- AKAP4 | c.1194G>T p.M398I | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV62074455; called by muse, mutect2, varscan2
- AKR1D1 | c.383G>T p.G128V | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54337201; called by muse, mutect2, varscan2
- ALG10 | c.155A>T p.H52L | Missense Mutation (SNP) | VAF 40/430 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV56792587; called by muse, mutect2
- ALG10 | c.311G>C p.S104T | Missense Mutation (SNP) | VAF 31/319 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.28); catalogued as COSV56792602; called by muse, mutect2
- ALG8 | c.647C>G p.S216C | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.076); catalogued as rs886048687, COSV55200425; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALKBH3 | c.732G>C p.L244F | Missense Mutation (SNP) | VAF 34/204 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV57024106; called by muse, mutect2, varscan2
- ALOX12 | c.749G>A p.R250K | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.368); catalogued as COSV52349732; called by muse, mutect2, varscan2
- ALPK2 | c.5723G>T p.S1908I | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100864502; called by muse, mutect2, varscan2
- AMER1 | c.1737G>T p.E579D | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV57660921; called by muse, mutect2, varscan2
- AMOT | c.2401C>A p.H801N (on ENST00000371959 / NM_001113490.1; = p.H392N on NM_133265.3) | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100495365, COSV59063376; called by muse, mutect2
- ANGEL1 | c.1432G>T p.A478S | Missense Mutation (SNP) | VAF 52/244 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as COSV51873377; called by muse, mutect2, varscan2
- ANK1 | c.3962A>T p.N1321I | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV55881874; called by muse, mutect2, varscan2
- ANK2 | c.3389G>T p.S1130I | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV52161632; called by muse, varscan2
- ANK2 | c.6940G>T p.G2314C | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.009); catalogued as COSV52161652; called by muse, mutect2, varscan2
- ANKRD27 | c.2656-1G>T p.X886_splice | Splice Site (SNP) | VAF 18/78 reads (23%) | catalogued as COSV100042934; called by muse, mutect2, varscan2
- ANKRD30A | c.3487C>A p.Q1163K (on ENST00000611781; = p.Q1107K on NM_052997.2) | Missense Mutation (SNP) | VAF 55/265 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.021); catalogued as COSV100653796, COSV64614228; called by muse, mutect2, varscan2
- ANO5 | c.1088G>T p.W363L | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV61085083; called by muse, mutect2, varscan2
- ANXA11 | c.905G>T p.R302L | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs140133265, COSV99627232; called by muse, mutect2, varscan2
- AP002512.3 | c.1097C>A p.P366H | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.367); catalogued as rs1050088418, COSV54408074, COSV99687833; called by muse, mutect2, varscan2
- APCS | c.205T>C p.F69L | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99661365; called by muse, mutect2, varscan2
- APOB | c.4648C>A p.L1550M | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV51935541; called by muse, mutect2, varscan2
- APP | c.302G>T p.G101V | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as rs532382285, COSV100695946; called by muse, mutect2, varscan2
- ARHGAP32 | c.6097C>T p.P2033S (on ENST00000310343 / NM_001378025.1; = p.P1684S on NM_014715.4) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.997); catalogued as COSV100088196; called by muse, mutect2, varscan2
- ARHGAP36 | c.1559C>A p.P520H | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.425); catalogued as COSV52266861; called by muse, mutect2, varscan2
- ARHGEF5 | c.744G>T p.E248D | Missense Mutation (SNP) | VAF 30/256 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.081); catalogued as COSV99282915; called by muse, mutect2, varscan2
- ASAH2 | c.762G>T p.Q254H | Missense Mutation (SNP) | VAF 107/348 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.917); catalogued as rs753939262; called by muse, mutect2, varscan2
- ASB7 | c.616A>T p.T206S | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.874); catalogued as COSV58403792; called by muse, mutect2, varscan2
- ATP10B | c.1382-1G>T p.X461_splice | Splice Site (SNP) | VAF 16/98 reads (16%) | catalogued as COSV58778826; called by muse, mutect2, varscan2
- ATP2B3 | c.1426G>T p.G476C | Missense Mutation (SNP) | VAF 13/161 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99684905; called by muse, mutect2
- ATP6V1C1 | c.473+1G>T p.X158_splice | Splice Site (SNP) | VAF 9/116 reads (8%) | catalogued as COSV67777368, COSV67778038; called by muse, mutect2
- ATP8B1 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.075); catalogued as COSV52175901; called by muse, mutect2
- BACH2 | c.1499G>T p.C500F | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1203834121, COSV57592641; called by muse, mutect2, varscan2
- BAZ1A | c.2876G>C p.R959T | Missense Mutation (SNP) | VAF 19/189 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.15); catalogued as COSV62410250; called by muse, mutect2, varscan2
- BCL11A | c.913A>T p.M305L (on ENST00000335712 / NM_001365609.1; = p.M339L on NM_018014.4) | Missense Mutation (SNP) | VAF 49/162 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.455); catalogued as COSV59630199; called by muse, mutect2, varscan2
- BIRC6 | c.418C>T p.L140F | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV70199350; called by muse, mutect2, varscan2
- BMP3 | c.1292G>C p.G431A | Missense Mutation (SNP) | VAF 53/183 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51084396, COSV99262028; called by muse, mutect2, varscan2
- BPIFB3 | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV64957351; called by muse, mutect2, varscan2
- BPIFC | c.1503G>T p.W501C | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.541); catalogued as COSV53278808; called by muse, mutect2, varscan2
- BRAF | c.338G>T p.S113I | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as COSV56184190; called by muse, mutect2, varscan2
- BRINP3 | c.2294G>T p.C765F | Missense Mutation (SNP) | VAF 22/190 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV66524511; called by muse, mutect2, varscan2
- BRINP3 | c.685G>A p.V229I | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as COSV100819047; called by muse, mutect2, varscan2
- BRINP3 | c.544G>T p.A182S | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.996); catalogued as COSV66514914, COSV66524518; called by muse, mutect2, varscan2
- BTD | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 13/153 reads (8%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.006); catalogued as rs1310040913, COSV57729167; called by muse, mutect2
- BTN3A3 | c.1442C>G p.S481C | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55071989; called by muse, mutect2
- C16orf70 | c.65-1G>T p.X22_splice | Splice Site (SNP) | VAF 33/110 reads (30%) | catalogued as COSV54627271; called by muse, mutect2, varscan2
- C1QTNF8 | c.389C>A p.S130Y | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.914); catalogued as COSV100116431; called by muse, mutect2, varscan2
- C1orf74 | c.122G>C p.G41A | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as COSV50553128; called by muse, mutect2, varscan2
- CACNA1C | c.4881C>A p.Y1627* | Nonsense Mutation (SNP) | VAF 7/26 reads (27%) | catalogued as COSV59719675, COSV59721841; called by muse, mutect2, varscan2
- CACNA1H | c.2566C>A p.P856T | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61986444; called by muse, mutect2, varscan2
- CACNA1S | c.2333C>G p.S778C | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV62936832, COSV62939574; called by muse, mutect2, varscan2
- CACNA2D1 | c.862T>A p.F288I | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV62379814; called by muse, mutect2, varscan2
- CAPN2 | c.593G>T p.G198V | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770020884, COSV54335388, COSV54336190; called by muse, mutect2, varscan2
- CARMIL2 | c.392C>A p.P131H | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.921); catalogued as COSV58026371; called by muse, mutect2, varscan2
- CARNS1 | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.549); catalogued as COSV57130853; called by muse, mutect2, varscan2
- CASP2 | c.983G>T p.G328V | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60082290; called by muse, mutect2, varscan2
- CASP8AP2 | c.745G>T p.D249Y | Missense Mutation (SNP) | VAF 28/212 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs369918159; called by muse, mutect2, varscan2
- CATSPER2 | c.175G>T p.G59* | Nonsense Mutation (SNP) | VAF 29/120 reads (24%) | catalogued as COSV100391106, COSV58660859; called by muse, mutect2, varscan2
- CCDC106 | c.201G>T p.M67I | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as rs1382981596, COSV54401812; called by muse, mutect2, varscan2
- CCDC141 | c.3893C>A p.P1298H | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.019); catalogued as COSV99837007; called by muse, mutect2, varscan2
- CCDC141 | c.3611A>T p.E1204V | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as COSV55384719; called by muse, mutect2, varscan2
- CCDC39 | c.835T>C p.F279L | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV99869578; called by muse, mutect2
- CCDC73 | c.1652A>G p.H551R | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV100067817; called by muse, mutect2, varscan2
- CCER1 | c.255G>T p.W85C | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV62646613, COSV62646877; called by muse, mutect2, varscan2
- CCL22 | c.49G>A p.V17M | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.017); catalogued as COSV54660183; called by muse, mutect2, varscan2
- CCNB3 | c.555G>T p.E185D | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.014); catalogued as COSV52073852; called by muse, mutect2, varscan2
- CCS | c.489G>T p.R163= | Splice Region (SNP) | VAF 8/96 reads (8%) | catalogued as COSV59579125; called by muse, mutect2
- CCT7 | c.1250C>A p.S417Y | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99240908; called by muse, mutect2, varscan2
- CD207 | c.799G>T p.V267L | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.16); catalogued as COSV101338566; called by muse, mutect2
- CD207 | c.798G>T p.W266C | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101338569; called by muse, mutect2
- CD248 | c.1563T>A p.Y521* | Nonsense Mutation (SNP) | VAF 10/88 reads (11%) | catalogued as COSV60936501; called by muse, mutect2, varscan2
- CD33 | c.466G>T p.G156C | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51801870; called by muse, mutect2, varscan2
- CD86 | c.541G>T p.E181* (on ENST00000330540 / NM_175862.5; = p.E175* on NM_006889.4) | Nonsense Mutation (SNP) | VAF 19/118 reads (16%) | catalogued as COSV52606953; called by muse, mutect2, varscan2
- CDC20B | c.933G>T p.M311I | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.194); catalogued as COSV57052295; called by muse, mutect2, varscan2
- CDCP1 | c.324G>T p.E108D | Missense Mutation (SNP) | VAF 28/285 reads (10%) | SIFT tolerated (0.79); PolyPhen benign (0.041); catalogued as COSV56105494; called by muse, mutect2, varscan2
- CDH10 | c.344G>T p.R115M | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.471); catalogued as rs780636248, COSV52579582, COSV52581080; called by muse, mutect2, varscan2
- CDH10 | c.50C>A p.P17Q | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.066); catalogued as COSV52581087; called by muse, mutect2, varscan2
- CDH18 | c.151C>A p.P51T | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as COSV56923022; called by muse, mutect2, varscan2
- CDH6 | c.2279C>A p.A760E | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV54070182; called by muse, mutect2, varscan2
- CECR2 | c.820C>G p.L274V (on ENST00000342247 / NM_001290047.2; = p.L111V on NM_001290046.1) | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as COSV52841295; called by muse, mutect2, varscan2
- CENPC | c.1750G>C p.A584P | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV99894111; called by muse, mutect2, varscan2
- CENPE | c.4150A>G p.S1384G | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV54381268; called by muse, mutect2, varscan2
- CEP112 | c.2231G>T p.R744L | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV67139630; called by muse, mutect2
- CEP128 | c.2238G>T p.M746I | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV55377059; called by muse, mutect2, varscan2
- CEP250 | c.4688A>T p.E1563V | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.552); catalogued as COSV61170166; called by muse, mutect2, varscan2
- CFHR4 | c.216C>A p.C72* (on ENST00000367416 / NM_001201551.2; = p.C73* on NM_006684.5) | Nonsense Mutation (SNP) | VAF 11/171 reads (6%) | catalogued as rs1246360223, COSV52228741; called by muse, mutect2
- CHD6 | c.3332G>T p.R1111L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV58557210; called by muse, mutect2, varscan2
- CHD8 | c.4768G>T p.E1590* (on ENST00000646647 / NM_001170629.2; = p.E1311* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 89/436 reads (20%) | catalogued as rs1555314199, COSV63219132; called by muse, mutect2, varscan2
- CHGB | c.1069C>A p.L357M | Missense Mutation (SNP) | VAF 54/158 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.167); catalogued as COSV66760514; called by muse, mutect2, varscan2
- CHL1 | c.206G>T p.W69L | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56594107; called by muse, mutect2
- CHRND | c.221C>A p.T74N | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV51323192; called by muse, mutect2
- CHRND | c.1139C>T p.S380F | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51319277; called by muse, mutect2, varscan2
- CHSY3 | c.2539T>C p.Y847H | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV100519442; called by muse, mutect2, varscan2
- CLCN2 | c.85G>T p.D29Y | Missense Mutation (SNP) | VAF 48/141 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV55601183, COSV55603037; called by muse, mutect2, varscan2
- CLDN17 | c.135G>C p.R45S | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.593); catalogued as COSV54523053, COSV54523229; called by muse, mutect2, varscan2
- CLDN8 | c.103T>A p.F35I | Missense Mutation (SNP) | VAF 10/125 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99729882; called by muse, mutect2
- CLEC1B | c.440A>T p.E147V | Missense Mutation (SNP) | VAF 33/225 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as COSV53725508; called by muse, mutect2, varscan2
- CLVS1 | c.796T>G p.F266V | Missense Mutation (SNP) | VAF 22/201 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs1411168887, COSV57975062; called by muse, mutect2, varscan2
- CLYBL | c.230G>T p.G77V | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59221834; called by muse, mutect2, varscan2
- CNN3 | c.955G>C p.D319H | Missense Mutation (SNP) | VAF 16/169 reads (9%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.092); catalogued as COSV54730215; called by muse, mutect2, varscan2
- CNTNAP5 | c.1828G>T p.G610C | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV70486363; called by muse, mutect2
- COA7 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV65299517; called by muse, mutect2, varscan2
- COL13A1 | c.921C>A p.D307E (on ENST00000398978 / NM_001130103.2; = p.D250E on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.291); catalogued as COSV62569906; called by muse, mutect2
- COL1A1 | c.1135G>T p.A379S | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0.028); catalogued as COSV56804974, COSV99867805; called by muse, mutect2, varscan2
- COL24A1 | c.2029C>A p.P677T | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV65306506; called by muse, mutect2, varscan2
- COL4A1 | c.4277G>T p.G1426V | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101010940, COSV65425807; called by muse, mutect2, varscan2
- COL4A2 | c.952C>T p.Q318* | Nonsense Mutation (SNP) | VAF 18/97 reads (19%) | catalogued as rs768030086, COSV64628383; called by muse, mutect2, varscan2
- COL4A6 | c.1306G>T p.G436C | Missense Mutation (SNP) | VAF 66/218 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57866824; called by muse, mutect2, varscan2
- COL6A5 | c.7069C>A p.L2357M (on ENST00000312481; = p.L2353M on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.542); catalogued as COSV55202037; called by muse, mutect2, varscan2
- CORO1C | c.1213G>T p.V405F | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as COSV54595961; called by muse, mutect2
- CPB1 | c.310C>A p.Q104K | Missense Mutation (SNP) | VAF 37/148 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV51573505; called by muse, mutect2, varscan2
- CPE | c.443G>C p.S148T | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.72); PolyPhen benign (0.013); catalogued as COSV68580348; called by muse, mutect2, varscan2
- CPE | c.945C>A p.N315K | Missense Mutation (SNP) | VAF 72/447 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68580353; called by muse, mutect2, varscan2
- CPN2 | c.761C>A p.T254K | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT tolerated (0.66); PolyPhen benign (0.017); catalogued as COSV60470445; called by muse, mutect2, varscan2
- CPNE6 | c.1415G>C p.G472A | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53744183; called by muse, mutect2
- CR1 | c.3208C>A p.P1070T | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65458255; called by muse, varscan2
- CRISP1 | c.176C>A p.A59D | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100237090, COSV59993662; called by muse, mutect2, varscan2
- CSGALNACT2 | c.671G>T p.R224L | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65675490, COSV65675617; called by muse, mutect2, varscan2
- CSMD3 | c.10901C>T p.A3634V (on ENST00000297405 / NM_001363185.1; = p.A3465V on NM_052900.3) | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52172348; called by muse, mutect2, varscan2
- CSMD3 | c.10681G>T p.V3561L (on ENST00000297405 / NM_001363185.1; = p.V3392L on NM_052900.3) | Missense Mutation (SNP) | VAF 19/278 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV52145425; called by muse, mutect2
- CSMD3 | c.7754G>T p.G2585V (on ENST00000297405 / NM_001363185.1; = p.G2481V on NM_052900.3) | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs141864545, COSV99838070; called by muse, mutect2, varscan2
- CSMD3 | c.7753G>T p.G2585C (on ENST00000297405 / NM_001363185.1; = p.G2481C on NM_052900.3) | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99838074; called by muse, mutect2, varscan2
- CSMD3 | c.2456G>T p.G819V (on ENST00000297405 / NM_001363185.1; = p.G715V on NM_052900.3) | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs763936328, COSV52183731; called by muse, mutect2, varscan2
- CST1 | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.392); catalogued as COSV59054876; called by muse, mutect2, varscan2
- CTCF | c.1123G>A p.G375R | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50468940; called by muse, mutect2, varscan2
- CTNND2 | c.1515G>T p.Q505H | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV58878500; called by muse, mutect2
- CTSG | c.722C>G p.T241R | Missense Mutation (SNP) | VAF 35/341 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV53535493; called by muse, mutect2, varscan2
- CTXN3 | c.161A>G p.D54G | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV101060690; called by muse, mutect2, varscan2
- CUL3 | c.1843G>T p.E615* | Nonsense Mutation (SNP) | VAF 8/54 reads (15%) | catalogued as COSV52364897; called by muse, mutect2, varscan2
- CYB5R4 | c.31G>T p.A11S | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as COSV100859518; called by muse, mutect2, varscan2
- CYC1 | c.232C>G p.L78V | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.181); catalogued as rs756155043, COSV100010471; called by muse, mutect2, varscan2
- CYP2A13 | c.250C>T p.H84Y | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.06); catalogued as rs1345829055, COSV57837826; called by muse, mutect2, varscan2
- CYP2F1 | c.1006_1007del p.R336Afs*37 | Frame Shift Del (DEL) | VAF 5/25 reads (20%) | catalogued as rs754170770; called by pindel, varscan2
- CYP46A1 | c.283-2A>G p.X95_splice | Splice Site (SNP) | VAF 85/423 reads (20%) | catalogued as COSV55894557; called by muse, mutect2, varscan2
- CYP4F3 | c.1152C>A p.C384* | Nonsense Mutation (SNP) | VAF 18/139 reads (13%) | catalogued as COSV55409919, COSV55410605; called by muse, mutect2, varscan2
- DACH2 | c.746A>G p.E249G | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV64169139; called by muse, mutect2, varscan2
- DCAF12L2 | c.188G>T p.R63L | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as COSV100758920, COSV63581726; called by muse, mutect2, varscan2
- DCLRE1A | c.1090A>T p.S364C | Missense Mutation (SNP) | VAF 32/170 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV63748739; called by muse, mutect2, varscan2
- DDX24 | c.247G>T p.E83* | Nonsense Mutation (SNP) | VAF 12/130 reads (9%) | catalogued as COSV58212504; called by muse, mutect2
- DDX31 | c.1692G>T p.Q564H | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60135946; called by muse, mutect2, varscan2
- DEF8 | c.599A>T p.H200L (on ENST00000268676 / NM_207514.3; = p.H139L on NM_017702.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/172 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51919147; called by muse, mutect2, varscan2
- DEF8 | c.1003A>T p.S335C | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV51919169; called by muse, mutect2, varscan2
- DENND5A | c.595G>T p.D199Y | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60233689; called by muse, mutect2, varscan2
- DEPDC1 | c.1922G>C p.G641A (on ENST00000456315 / NM_001114120.3; = p.G357A on NM_017779.6) | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs374071985; called by muse, mutect2, varscan2
- DHFR2 | c.283G>T p.D95Y | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as COSV100113332; called by muse, mutect2, varscan2
- DIP2C | c.2413A>G p.N805D | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as rs1444301709, COSV55158482; called by muse, mutect2, varscan2
- DISP1 | c.1948A>G p.T650A | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.888); catalogued as COSV52659027; called by muse, mutect2, varscan2
- DLX2 | c.663C>A p.H221Q | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.446); catalogued as COSV52232141; called by muse, mutect2, varscan2
- DMD | c.8545A>G p.R2849G | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); catalogued as rs1267267091, COSV58911659; called by muse, mutect2
- DNAAF6 | c.577C>A p.P193T | Missense Mutation (SNP) | VAF 54/170 reads (32%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV60495835; called by muse, mutect2, varscan2
- DNAH17 | c.7346G>T p.W2449L | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.212); catalogued as COSV101102693; called by muse, mutect2
- DNAH5 | c.11117A>T p.E3706V | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54225178; called by muse, mutect2, varscan2
- DNHD1 | c.628G>A p.V210M | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.096); catalogued as rs1476186357, COSV54435846; called by muse, mutect2
- DOCK7 | c.3630G>C p.K1210N (on ENST00000635253 / NM_001367561.1; = p.K1179N on NM_033407.3) | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.968); catalogued as COSV52005756; called by muse, mutect2, varscan2
- DOCK9 | c.5142G>T p.M1714I (on ENST00000376460 / NM_001366676.2; = p.M1715I on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/183 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV59629582; called by muse, mutect2
- DPYS | c.1236G>C p.R412S | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1405459134, COSV100679786, COSV100679807, COSV100679871; called by muse, mutect2
- DPYSL3 | c.674T>A p.L225Q | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.955); catalogued as COSV58326825; called by muse, mutect2, varscan2
- DRC1 | c.1436C>T p.S479F | Missense Mutation (SNP) | VAF 25/191 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.592); catalogued as COSV56531393; called by muse, mutect2, varscan2
- DSCAML1 | c.3410C>G p.S1137C (on ENST00000321322; = p.S1077C on NM_020693.4) | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58390849; called by muse, mutect2
- DSG1 | c.2649G>T p.M883I | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57135341; called by muse, mutect2, varscan2
- DUOX2 | c.3817A>T p.S1273C | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV66532167; called by muse, mutect2, varscan2
- DUSP9 | c.580C>A p.P194T | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.59); PolyPhen benign (0.086); catalogued as COSV61437994; called by muse, mutect2, varscan2
- E2F7 | c.2355G>T p.L785F | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs745894339, COSV59740047; called by muse, mutect2, varscan2
- ECPAS | c.1843G>T p.D615Y | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV52197354; called by muse, mutect2, varscan2
- EDN3 | c.637C>A p.P213T (on ENST00000337938 / NM_001302455.2; = p.P199T on NM_207033.3) | Missense Mutation (SNP) | VAF 23/242 reads (10%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.084); catalogued as COSV61108005; called by muse, mutect2
- EEF1AKMT4-ECE2 | c.700C>A p.P234T | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62567906; called by muse, mutect2, varscan2
- EFCAB12 | c.388C>G p.P130A | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.218); catalogued as COSV58176335; called by muse, mutect2, varscan2
- EFCAB5 | c.4412T>C p.I1471T | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as COSV57930126; called by muse, mutect2, varscan2
- EFTUD2 | c.2439G>C p.R813S | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53655621; called by muse, mutect2, varscan2
- ELFN2 | c.1013C>A p.T338N | Missense Mutation (SNP) | VAF 31/242 reads (13%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as COSV68744586; called by muse, mutect2, varscan2
- ELOA2 | c.43C>A p.Q15K | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV99797010; called by muse, mutect2, varscan2
- ELSPBP1 | c.110G>A p.G37E | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.874); catalogued as COSV60413711, COSV60413980; called by muse, mutect2
- ENGASE | c.1700+1G>A p.X567_splice | Splice Site (SNP) | VAF 5/42 reads (12%) | catalogued as COSV56135543; called by muse, mutect2
- ENOX1 | c.893G>C p.R298P | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54894307, COSV54899477; called by muse, mutect2, varscan2
- EPN2 | c.1584G>T p.R528S | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.034); catalogued as COSV59061242; called by muse, mutect2, varscan2
- ESRRB | c.218G>T p.R73L | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as COSV55061196, COSV55061619; called by muse, mutect2, varscan2
- EVI2B | c.1327C>A p.P443T | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100445539; called by muse, mutect2
- EVPL | c.1391G>T p.C464F | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56911034; called by muse, mutect2, varscan2
- EYA1 | c.901G>T p.G301W | Missense Mutation (SNP) | VAF 32/383 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as COSV58160277; called by muse, mutect2
- FAHD2B | c.724G>T p.E242* | Nonsense Mutation (SNP) | VAF 18/126 reads (14%) | catalogued as COSV55630679; called by muse, mutect2, varscan2
- FAM135A | c.3031G>C p.E1011Q (on ENST00000370479 / NM_001351599.1; = p.E798Q on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.432); catalogued as COSV52051610; called by muse, mutect2, varscan2
- FAM13C | c.496G>T p.D166Y | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV53248501; called by muse, mutect2, varscan2
- FAM171A1 | c.2593G>T p.D865Y | Missense Mutation (SNP) | VAF 36/218 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.305); catalogued as COSV65316156, COSV65317426; called by muse, mutect2, varscan2
- FAM47A | c.2238G>C p.K746N | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100649747, COSV60496724, COSV60498855; called by muse, mutect2, varscan2
- FANCM | c.5014G>A p.D1672N | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as rs1016099459, COSV57501278; called by muse, mutect2, varscan2
- FASN | c.3238G>T p.V1080L | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as COSV60754886; called by muse, mutect2
- FAT2 | c.10481A>T p.Q3494L | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as rs1210627644, COSV55819862; called by muse, mutect2, varscan2
- FAT3 | c.230G>T p.W77L | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.069); catalogued as rs573991535, COSV53111202, COSV99972075; called by muse, mutect2, varscan2
- FAT3 | c.6943G>T p.D2315Y | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1447557458, COSV53111232; called by muse, mutect2, varscan2
- FAT3 | c.12814C>T p.R4272C | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs1438591331, COSV53111253; called by muse, mutect2, varscan2
- FAT4 | c.3934A>T p.T1312S | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as COSV67886852; called by muse, mutect2, varscan2
- FBN2 | c.1084A>T p.R362* | Nonsense Mutation (SNP) | VAF 16/49 reads (33%) | catalogued as COSV52513670; called by muse, mutect2, varscan2
- FCRL5 | c.2408C>A p.A803E | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.338); catalogued as COSV62511437, COSV62514578; called by muse, mutect2, varscan2
- FER1L6 | c.3289G>T p.A1097S | Missense Mutation (SNP) | VAF 66/173 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV67549939; called by muse, mutect2, varscan2
- FGF14 | c.325G>T p.V109L | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.989); catalogued as COSV65943974; called by muse, mutect2, varscan2
- FHDC1 | c.2186G>C p.R729T | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV52599697; called by muse, mutect2, varscan2
- FHOD3 | c.1029G>T p.R343S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV57173577; called by muse, mutect2, varscan2
- FLG | c.1735G>T p.D579Y | Missense Mutation (SNP) | VAF 60/926 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64237433; called by muse, mutect2
- FLG | c.1250C>G p.S417C | Missense Mutation (SNP) | VAF 102/766 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs757753733, COSV64241926; called by muse, mutect2, varscan2
- FLT1 | c.1004C>A p.T335N | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV56719668; called by muse, mutect2, varscan2
- FNDC7 | c.1351C>T p.P451S | Missense Mutation (SNP) | VAF 13/207 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54753755; called by muse, mutect2
- FNIP2 | c.770G>A p.S257N | Missense Mutation (SNP) | VAF 63/489 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.166); catalogued as COSV52439895; called by muse, mutect2, varscan2
- FOLH1 | c.2104G>A p.G702R | Missense Mutation (SNP) | VAF 37/180 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV57049272; called by muse, mutect2, varscan2
- FOXG1 | c.1278G>T p.M426I | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV57394913, COSV57396826; called by muse, mutect2, varscan2
- FSHR | c.2011C>A p.H671N | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.258); catalogued as COSV100437452; called by mutect2, varscan2
- FSHR | c.1231A>G p.I411V | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.13); catalogued as COSV58623867; called by muse, mutect2
- FSTL5 | c.2007C>A p.S669R | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.102); catalogued as COSV60196021, COSV60223489; called by muse, mutect2, varscan2
- FTMT | c.58C>A p.R20S | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.068); catalogued as rs372731129, COSV58420377; called by muse, mutect2, varscan2
- GABRA6 | c.1310G>T p.W437L | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50881580; called by muse, mutect2, varscan2
- GABRQ | c.1135C>A p.Q379K | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV64782064; called by muse, mutect2, varscan2
- GADL1 | c.1102G>T p.D368Y | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56978852, COSV56978895; called by muse, mutect2, varscan2
- GAL3ST4 | c.866G>C p.W289S | Missense Mutation (SNP) | VAF 19/217 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.371); catalogued as COSV57586431; called by muse, mutect2
- GALNT1 | c.1490G>T p.C497F | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52452351; called by muse, mutect2, varscan2
- GALNT16 | c.864-2A>T p.X288_splice | Splice Site (SNP) | VAF 12/53 reads (23%) | catalogued as COSV61886034; called by muse, mutect2, varscan2
- GALNTL6 | c.128G>T p.G43V | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV72552982; called by muse, mutect2, varscan2
- GALNTL6 | c.559C>A p.L187M | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV72491029; called by muse, mutect2, varscan2
- GAN | c.860A>G p.K287R | Missense Mutation (SNP) | VAF 19/213 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as COSV73720901; called by muse, mutect2
- GBX2 | c.950C>A p.P317H | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV60445270; called by muse, mutect2
- GCNT2 | c.1173G>T p.Q391H (on ENST00000379597 / NM_001374747.1; = p.Q389H on NM_001491.3) | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV53942348; called by muse, mutect2, varscan2
- GDPD4 | c.49G>T p.D17Y | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV60019412; called by muse, mutect2, varscan2
- GLDC | c.2875C>A p.H959N | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs757705918, COSV58680124; called by muse, mutect2, varscan2
- GPC2 | c.564C>A p.Y188* | Nonsense Mutation (SNP) | VAF 17/66 reads (26%) | catalogued as COSV52785086; called by muse, mutect2, varscan2
- GPC3 | c.1516A>T p.I506F | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.284); catalogued as COSV63664299; called by muse, mutect2, varscan2
- GPC6 | c.946G>T p.D316Y | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as COSV65512233; called by muse, mutect2, varscan2
- GPR158 | c.2338G>T p.G780C | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs369542883, COSV66270468; called by muse, mutect2, varscan2
- GPR158 | c.3118C>A p.P1040T | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.69); PolyPhen benign (0.033); catalogued as COSV66265748, COSV66280641; called by muse, mutect2, varscan2
- GPR179 | c.3854G>A p.G1285D (on ENST00000621958; = p.G1284D on NM_001004334.4) | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1349066788; called by muse, mutect2
- GRHL1 | c.514C>A p.P172T | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV61408239; called by muse, mutect2
- GRID2 | c.1467C>A p.Y489* | Nonsense Mutation (SNP) | VAF 13/61 reads (21%) | catalogued as COSV56207010, COSV56233184; called by muse, mutect2, varscan2
- GRIN2B | c.2567G>T p.G856V | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV74205955; called by muse, mutect2, varscan2
- GRK3 | c.747+1G>C p.X249_splice | Splice Site (SNP) | VAF 6/90 reads (7%) | catalogued as COSV60795863; called by muse, mutect2
- GRK4 | c.971-1G>T p.X324_splice (on ENST00000398052 / NM_182982.3; = p.X292_splice on NM_005307.3) | Splice Site (SNP) | VAF 15/112 reads (13%) | catalogued as COSV100584113; called by muse, mutect2, varscan2
- GRK4 | c.971G>T p.G324V (on ENST00000398052 / NM_182982.3; = p.G292V on NM_005307.3) | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV100584114; called by muse, mutect2, varscan2
- GRM1 | c.3459C>A p.D1153E | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV51149372; called by muse, varscan2
- GRM3 | c.172G>A p.G58R | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64471897, COSV64478074; called by muse, mutect2, varscan2
- GRM4 | c.1111C>A p.H371N | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100946407; called by muse, mutect2, varscan2
- GRM4 | c.1110C>A p.F370L | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV100946416; called by muse, mutect2, varscan2
- GSDMD | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.582); catalogued as COSV52797219; called by muse, mutect2, varscan2
- HAND2 | c.271G>T p.G91C | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.894); catalogued as COSV100854200; called by muse, mutect2, varscan2
- HARS2 | c.1097G>T p.G366V | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV51227021; called by muse, mutect2
- HCFC2 | c.2071G>A p.E691K | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as COSV57558685; called by muse, mutect2, varscan2
- HDAC7 | c.1232C>T p.T411I (on ENST00000427332; = p.T450I on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/164 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.397); catalogued as COSV50353398; called by muse, mutect2, varscan2
- HECTD3 | c.2153T>A p.M718K | Missense Mutation (SNP) | VAF 30/206 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV64670182; called by muse, mutect2, varscan2
- HELZ | c.2357-1G>T p.X786_splice | Splice Site (SNP) | VAF 44/197 reads (22%) | catalogued as COSV62378530; called by muse, mutect2, varscan2
- HGF | c.1765G>C p.V589L | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV55948401, COSV55949708; called by muse, mutect2, varscan2
- HGF | c.923G>T p.G308V | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55949722, COSV55959952; called by muse, mutect2
- HHIPL2 | c.1027C>A p.L343I | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV58565228; called by muse, mutect2
- HJURP | c.1726C>A p.R576S | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.224); catalogued as COSV64978806, COSV64979720; called by muse, mutect2, varscan2
- HMGCS2 | c.1081C>G p.Q361E | Missense Mutation (SNP) | VAF 57/754 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV65567900; called by muse, mutect2
- HMMR | c.878G>T p.C293F | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); catalogued as COSV100701018; called by muse, mutect2, varscan2
- HNF4G | c.641G>T p.R214L (on ENST00000354370 / NM_001330561.2; = p.R261L on NM_004133.5) | Missense Mutation (SNP) | VAF 115/276 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.055); catalogued as COSV62968669; called by muse, mutect2, varscan2
- HNF4G | c.983-1G>T p.X328_splice (on ENST00000354370 / NM_001330561.2; = p.X375_splice on NM_004133.5) | Splice Site (SNP) | VAF 33/76 reads (43%) | catalogued as COSV62968678; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.159G>C p.M53I (on ENST00000354667 / NM_031243.3; = p.M41I on NM_002137.4) | Missense Mutation (SNP) | VAF 11/150 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV61159064; called by muse, mutect2
- HOXA2 | c.874C>A p.P292T | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV56066333; called by muse, mutect2, varscan2
- HOXA7 | c.193C>A p.P65T | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.277); catalogued as rs1384986017, COSV54217748, COSV54217811; called by mutect2, varscan2
- HSD11B1 | c.295G>C p.A99P | Missense Mutation (SNP) | VAF 42/279 reads (15%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.585); catalogued as rs200402963, COSV54825830, COSV99808217; called by muse, mutect2, varscan2
- HSD17B6 | c.627C>G p.F209L | Missense Mutation (SNP) | VAF 8/223 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV59107044, COSV59107326; called by muse, mutect2
- ICE1 | c.5069G>A p.R1690H | Missense Mutation (SNP) | VAF 50/196 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs749805448, COSV56825189; called by muse, mutect2, varscan2
- IFI16 | c.661C>G p.P221A | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV55534145; called by muse, mutect2
- IFT88 | c.569A>T p.Q190L (on ENST00000319980 / NM_001318493.2; = p.Q181L on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60673424; called by muse, mutect2
- IGF2R | c.1878C>G p.N626K | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV63629231; called by muse, mutect2, varscan2
- IL17RA | c.511G>T p.G171W | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60053264; called by muse, mutect2, varscan2
- IL18R1 | c.1112-2A>G p.X371_splice | Splice Site (SNP) | VAF 8/88 reads (9%) | catalogued as rs1200486634, COSV52124623; called by muse, mutect2
- IL1RL1 | c.15C>G p.I5M | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.288); catalogued as COSV99294220; called by muse, mutect2, varscan2
- IL31RA | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.011); catalogued as COSV51681659; called by muse, mutect2, varscan2
- IMPG1 | c.377G>T p.W126L | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100886465; called by muse, mutect2, varscan2
- IMPG1 | c.376T>G p.W126G | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100886469; called by muse, mutect2, varscan2
- INTS6 | c.1084G>T p.G362C | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as COSV60878108; called by muse, mutect2, varscan2
- IRX4 | c.1342C>A p.L448I | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.158); catalogued as COSV51475338, COSV99180834; called by muse, mutect2
- ITGA3 | c.1842G>T p.E614D | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.849); catalogued as COSV50311947; called by muse, mutect2, varscan2
- ITGA4 | c.817C>A p.P273T | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99276483; called by muse, mutect2, varscan2
- ITGA4 | c.818C>A p.P273H | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99276488; called by muse, mutect2, varscan2
- ITGA8 | c.380C>A p.P127H | Missense Mutation (SNP) | VAF 32/143 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV65228999; called by muse, mutect2, varscan2
- ITGB3 | c.191G>C p.C64S | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM099784, COSV71384061; called by muse, mutect2, varscan2
- ITIH1 | c.959G>T p.G320V | Missense Mutation (SNP) | VAF 7/144 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.493); catalogued as COSV56255047; called by muse, mutect2
- IVD | c.1012G>A p.A338T (on ENST00000651168; = p.A335T on NM_002225.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV51099199; called by muse, mutect2, varscan2
- JAZF1 | c.116-1G>C p.X39_splice | Splice Site (SNP) | VAF 10/89 reads (11%) | catalogued as COSV52240371, COSV99386757; called by muse, mutect2, varscan2
- KCNH1 | c.2590G>A p.E864K (on ENST00000271751 / NM_172362.3; = p.E837K on NM_002238.4) | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs148523415; called by muse, mutect2, varscan2
- KCNK10 | c.1397C>T p.P466L | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV56644464, COSV56650420; called by muse, mutect2, varscan2
- KCNQ2 | c.1508C>T p.S503L (on ENST00000359125 / NM_172107.4; = p.S475L on NM_004518.6) | Missense Mutation (SNP) | VAF 23/176 reads (13%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.95); catalogued as COSV60545101; called by muse, mutect2, varscan2
- KCNQ2 | c.1113G>A p.M371I | Missense Mutation (SNP) | VAF 59/220 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); catalogued as COSV60434114; called by muse, mutect2, varscan2
- KCNQ5 | c.1979C>A p.P660H | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV59660308; called by muse, mutect2, varscan2
- KDF1 | c.328A>T p.S110C | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); catalogued as COSV57671383; called by muse, mutect2, varscan2
- KDM3B | c.1633G>C p.E545Q | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.638); catalogued as COSV100069274, COSV58690782; called by muse, mutect2, varscan2
- KDM4C | c.921+1G>C p.X307_splice | Splice Site (SNP) | VAF 12/136 reads (9%) | catalogued as COSV67186552; called by muse, mutect2
- KIAA1109 | c.9167G>T p.G3056V | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99166238; called by muse, mutect2, varscan2
- KIAA1549L | c.725G>C p.R242T (on ENST00000321505; = p.R539T on NM_012194.3) | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV55773946; called by muse, mutect2, varscan2
- KIAA1755 | c.2099C>A p.P700H | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99642247; called by muse, mutect2
- KIF13A | c.5101G>T p.E1701* | Nonsense Mutation (SNP) | VAF 36/70 reads (51%) | catalogued as COSV52451514; called by muse, mutect2, varscan2
- KIF1A | c.4630G>A p.E1544K (on ENST00000320389 / NM_001379639.1; = p.E1536K on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.207); catalogued as rs377032453; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIF4B | c.1517G>A p.R506K | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV70529330; called by muse, mutect2, varscan2
- KIF4B | c.2998G>T p.A1000S | Missense Mutation (SNP) | VAF 16/163 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV70529338; called by muse, mutect2
- KLF10 | c.385C>T p.H129Y | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as COSV53435566; called by muse, mutect2
- KLHDC10 | c.1319G>T p.R440L | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59050688, COSV59051738; called by muse, mutect2, varscan2
- KLHL1 | c.451G>T p.E151* | Nonsense Mutation (SNP) | VAF 25/148 reads (17%) | catalogued as COSV64772631; called by muse, mutect2, varscan2
- KLHL10 | c.335T>A p.L112Q | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53173206; called by muse, mutect2, varscan2
- KRT35 | c.1212G>T p.E404D | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV99877820; called by muse, varscan2
- KRT72 | c.325C>A p.P109T | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs888721644, COSV53372990; called by muse, mutect2, varscan2
- KRTAP19-7 | c.80G>T p.C27F | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.221); catalogued as COSV58366170; called by muse, mutect2, varscan2
- KRTAP24-1 | c.377G>T p.G126V | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1261342571, COSV100447463; called by muse, mutect2, varscan2
- KRTAP5-3 | c.89G>A p.G30D | Missense Mutation (SNP) | VAF 23/219 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.466); catalogued as rs1457664675, COSV101294515; called by muse, mutect2, varscan2
- KRTAP6-3 | c.197G>T p.G66V | Missense Mutation (SNP) | VAF 6/34 reads (18%) | PolyPhen probably damaging (0.982); catalogued as COSV101196498, COSV66963111; called by mutect2, varscan2
- KRTAP9-4 | c.126C>A p.C42* | Nonsense Mutation (SNP) | VAF 15/63 reads (24%) | catalogued as rs762012538, COSV61898074; called by muse, mutect2, varscan2
- KRTAP9-8 | c.111C>A p.C37* | Nonsense Mutation (SNP) | VAF 13/147 reads (9%) | catalogued as COSV54199916; called by muse, mutect2
- L1CAM | c.2548-1G>T p.X850_splice | Splice Site (SNP) | VAF 60/162 reads (37%) | catalogued as COSV62828140; called by muse, mutect2, varscan2
- L1CAM | c.1075A>T p.R359W | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); catalogued as COSV62828144; called by muse, mutect2, varscan2
- LAMA2 | c.1604G>T p.G535V | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV101370593; called by mutect2, varscan2
- LARS2 | c.1147G>T p.D383Y | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV55527695; called by muse, mutect2
- LCN15 | c.68T>A p.L23Q | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.928); catalogued as COSV100293467; called by muse, mutect2, varscan2
- LEF1 | c.628C>G p.P210A | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.803); catalogued as rs1194536526, COSV54467369; called by muse, mutect2, varscan2
- LEPR | c.2673G>T p.K891N | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100756384, COSV60755165; called by muse, mutect2
- LIG1 | c.139T>A p.S47T | Missense Mutation (SNP) | VAF 44/183 reads (24%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.012); catalogued as COSV54391821; called by muse, mutect2, varscan2
- LIMCH1 | c.536A>T p.Y179F | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV58283952; called by muse, mutect2, varscan2
- LIMD2 | c.237C>A p.Y79* | Nonsense Mutation (SNP) | VAF 15/89 reads (17%) | catalogued as COSV99368637; called by muse, mutect2, varscan2
- LMBRD1 | c.1100G>T p.G367V (on ENST00000649011; = p.G345V on NM_018368.4) | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100992630; called by muse, mutect2, varscan2
- LMBRD1 | c.1099G>A p.G367R (on ENST00000649011; = p.G345R on NM_018368.4) | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV65300319; called by muse, mutect2, varscan2
- LRP1 | c.8474G>T p.C2825F | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99676271; called by muse, mutect2, varscan2
- LRP1 | c.8475C>G p.C2825W | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99676273; called by muse, mutect2, varscan2
- LRP1B | c.10574G>C p.G3525A | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67221180, COSV99081275; called by muse, mutect2, varscan2
- LRP1B | c.530C>A p.T177N | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.041); catalogued as COSV67221186; called by muse, mutect2, varscan2
- LRP2 | c.1817G>C p.G606A | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.042); catalogued as COSV55553545; called by muse, mutect2, varscan2
- LRRC4C | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 5/63 reads (8%) | catalogued as COSV53425933; called by muse, mutect2
- LRRC7 | c.2662A>T p.S888C (on ENST00000651989 / NM_001370785.2; = p.S855C on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50459623; called by muse, mutect2, varscan2
- LRRTM1 | c.853C>A p.L285M | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54441237; called by muse, mutect2, varscan2
- LY75 | c.3629A>C p.D1210A | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.345); catalogued as COSV55105682; called by muse, mutect2, varscan2
- LYST | c.9682G>T p.V3228L | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV67702884, COSV67707055; called by muse, mutect2
- MAGEC2 | c.254G>T p.S85I | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.365); catalogued as COSV55999394; called by muse, mutect2, varscan2
- MARCHF6 | c.1292A>G p.Y431C | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.243); catalogued as COSV56881485; called by muse, mutect2
- MARCO | c.43G>T p.E15* | Nonsense Mutation (SNP) | VAF 10/118 reads (8%) | catalogued as COSV100503635, COSV59054432; called by muse, mutect2
- MAS1L | c.1075C>T p.H359Y | Missense Mutation (SNP) | VAF 67/138 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs760795567, COSV65808937; called by muse, mutect2, varscan2
- MDC1 | c.2809G>T p.V937L | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.019); catalogued as COSV64524624; called by muse, mutect2, varscan2
- MDFIC | c.227A>T p.Q76L | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.503); catalogued as COSV57563883; called by muse, mutect2, varscan2
- MED6 | c.517C>T p.Q173* | Nonsense Mutation (SNP) | VAF 16/160 reads (10%) | catalogued as COSV56450223; called by muse, mutect2, varscan2
- MEGF8 | c.8218G>T p.A2740S (on ENST00000251268 / NM_001271938.2; = p.A2673S on NM_001410.3) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.173); catalogued as COSV52084973; called by muse, mutect2, varscan2
- MEX3B | c.653G>T p.R218L | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61663453; called by muse, mutect2, varscan2
- MFSD11 | c.261-1G>T p.X87_splice | Splice Site (SNP) | VAF 32/329 reads (10%) | catalogued as COSV60623920; called by muse, mutect2
- MGA | c.7140G>T p.P2380= (on ENST00000219905 / NM_001164273.1; = p.P2171= on NM_001080541.2) | Splice Region (SNP) | VAF 21/76 reads (28%) | catalogued as COSV99580445; called by muse, mutect2, varscan2
- MGAT5B | c.2310G>T p.K770N (on ENST00000569840 / NM_001199172.2; = p.K768N on NM_144677.3) | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); catalogued as COSV56929408; called by muse, mutect2
- MLLT10 | c.1429G>T p.G477W | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56996028; called by muse, mutect2, varscan2
- MMP16 | c.946G>T p.D316Y | Missense Mutation (SNP) | VAF 20/264 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV54165465; called by muse, mutect2
- MMP2 | c.1529C>T p.A510V | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as COSV54601408; called by muse, mutect2, varscan2
- MPP6 | c.927G>T p.M309I | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV56042916, COSV99757614; called by muse, mutect2, varscan2
- MS4A14 | c.1834C>A p.Q612K | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.019); catalogued as COSV100280530; called by muse, mutect2, varscan2
- MS4A6A | c.359G>T p.G120V | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.14); catalogued as COSV100124502, COSV100124941, COSV60618722; called by muse, mutect2, varscan2
- MSMO1 | c.673A>C p.I225L | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV54970242; called by muse, mutect2, varscan2
- MTPN | c.271-1G>T p.X91_splice | Splice Site (SNP) | VAF 16/141 reads (11%) | catalogued as COSV101262977; called by muse, mutect2, varscan2
- MTR | c.1998G>T p.W666C | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63964941; called by muse, mutect2, varscan2
- MUC16 | c.26395C>A p.Q8799K | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.444); catalogued as rs569169440, COSV67466478; called by muse, mutect2, varscan2
- MUC5B | c.13391G>A p.G4464E | Missense Mutation (SNP) | VAF 35/189 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as COSV71590412; called by muse, mutect2, varscan2
- MXRA5 | c.80G>T p.C27F | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99477651; called by muse, mutect2, varscan2
- MYH11 | c.3160G>T p.E1054* | Nonsense Mutation (SNP) | VAF 13/79 reads (16%) | catalogued as COSV55553499; called by muse, mutect2, varscan2
- MYH13 | c.3952G>T p.E1318* | Nonsense Mutation (SNP) | VAF 9/30 reads (30%) | catalogued as COSV52829068; called by muse, mutect2, varscan2
- MYH8 | c.3551C>A p.A1184D | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); catalogued as COSV67965250; called by muse, mutect2
- MYO18B | c.6470G>T p.R2157M | Missense Mutation (SNP) | VAF 46/148 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV59134625; called by muse, mutect2, varscan2
- MYO1A | c.1441C>T p.H481Y | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV55654035; called by muse, mutect2, varscan2
- MYOD1 | c.916C>T p.Q306* | Nonsense Mutation (SNP) | VAF 5/41 reads (12%) | catalogued as COSV100000298; called by muse, varscan2
- MYOM2 | c.2965G>T p.G989* | Nonsense Mutation (SNP) | VAF 5/19 reads (26%) | catalogued as rs777160311, COSV50713347; called by muse, mutect2, varscan2
- MYT1L | c.2716C>A p.P906T | Missense Mutation (SNP) | VAF 41/174 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67720457; called by muse, mutect2, varscan2
- MYT1L | c.1297C>A p.L433M | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67720462; called by muse, mutect2, varscan2
- NAIP | c.281G>C p.G94A | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.545); catalogued as COSV52001084, COSV52001391, COSV52002145; called by muse, mutect2, varscan2
- NAP1L3 | c.218G>C p.R73P | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV59075376; called by muse, mutect2
- NAV3 | c.2449G>T p.V817L | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV99892506; called by muse, mutect2, varscan2
- NCAM1 | c.1765C>A p.L589I (on ENST00000316851 / NM_181351.5; = p.L579I on NM_000615.7) | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as COSV100377975; called by muse, mutect2
- NCKAP1 | c.1499C>G p.S500* | Nonsense Mutation (SNP) | VAF 7/69 reads (10%) | catalogued as COSV62941190; called by muse, mutect2, varscan2
- NCSTN | c.1195G>T p.A399S | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV54186353, COSV54187651; called by muse, mutect2, varscan2
- NDUFAF4 | c.518G>T p.R173L | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs745521317; called by mutect2, varscan2
- NELL2 | c.289del p.H97Tfs*2 | Frame Shift Del (DEL) | VAF 22/96 reads (23%) | catalogued as COSV100420230; called by mutect2, pindel, varscan2
- NES | c.3718G>T p.E1240* | Nonsense Mutation (SNP) | VAF 54/218 reads (25%) | catalogued as COSV63961101; called by muse, mutect2, varscan2
- NETO1 | c.722G>T p.S241I | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV55006935; called by muse, mutect2, varscan2
- NFATC4 | c.2551G>T p.E851* | Nonsense Mutation (SNP) | VAF 24/92 reads (26%) | catalogued as COSV51602964; called by muse, mutect2, varscan2
- NIPAL4 | c.556G>T p.A186S | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV61730035; called by muse, mutect2
- NKX6-1 | c.232G>T p.G78W | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.996); catalogued as COSV55684267; called by muse, mutect2, varscan2
- NLGN1 | c.1110G>T p.Q370H | Missense Mutation (SNP) | VAF 90/217 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); catalogued as rs1426206481, COSV64334009; called by muse, mutect2, varscan2
- NLRP7 | c.1207C>A p.P403T | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.057); catalogued as COSV60174584; called by muse, mutect2, varscan2
- NLRX1 | c.753C>G p.F251L | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52704595; called by muse, mutect2, varscan2
- NLRX1 | c.859C>A p.L287M | Missense Mutation (SNP) | VAF 36/214 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52704628; called by muse, mutect2, varscan2
- NOTCH2 | c.3691C>G p.R1231G | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV56691620, COSV56702539; called by muse, mutect2, varscan2
- NOXRED1 | c.348G>T p.L116= | Splice Region (SNP) | VAF 7/32 reads (22%) | catalogued as COSV53628039; called by muse, mutect2, varscan2
- NPNT | c.1137G>T p.Q379H | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as COSV59753850; called by muse, mutect2, varscan2
- NR1I2 | c.27G>T p.W9C | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.439); catalogued as COSV61978005, COSV61978348; called by muse, mutect2
- NR1I3 | c.407G>A p.R136K | Missense Mutation (SNP) | VAF 34/308 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.04); catalogued as COSV63467893; called by muse, mutect2, varscan2
- NRAP | c.1042C>A p.H348N | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT tolerated (0.75); PolyPhen benign (0.347); catalogued as COSV63490633; called by muse, mutect2, varscan2
- NRCAM | c.875G>C p.C292S (on ENST00000379028 / NM_001371124.1; = p.C286S on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV61037111; called by muse, mutect2, varscan2
- NRXN1 | c.358C>A p.R120S | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101277713, COSV68008082, COSV68010230; called by mutect2, varscan2
- NSF | c.1514A>C p.N505T | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as COSV56574921; called by muse, mutect2, varscan2
- NTNG1 | c.913G>C p.V305L | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT tolerated (0.86); PolyPhen benign (0.005); catalogued as COSV53971836; called by muse, mutect2, varscan2
- NTRK3 | c.1863G>T p.K621N | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100712534, COSV62304520; called by muse, mutect2, varscan2
- NTSR1 | c.230G>T p.G77V | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs994048236, COSV65138645; called by muse, mutect2, varscan2
- OLFM4 | c.903G>C p.E301D | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.74); PolyPhen benign (0.02); catalogued as COSV54577416; called by muse, mutect2, varscan2
- OMA1 | c.1077G>T p.W359C | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62255547; called by muse, mutect2, varscan2
- OPRM1 | c.349G>T p.A117S | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.536); catalogued as COSV57676989; called by muse, mutect2, varscan2
- OR10H5 | c.119T>G p.L40R | Missense Mutation (SNP) | VAF 36/171 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV100454723; called by muse, mutect2, varscan2
- OR10J3 | c.338G>T p.C113F | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV59954342; called by muse, mutect2, varscan2
- OR10K1 | c.898G>T p.A300S | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV56872001, COSV56872750; called by muse, mutect2, varscan2
- OR10R2 | c.427T>A p.Y143N | Missense Mutation (SNP) | VAF 37/296 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV63768768; called by muse, mutect2, varscan2
- OR10Z1 | c.575C>A p.T192K | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV63524869; called by muse, mutect2, varscan2
- OR11L1 | c.604C>A p.L202M | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV63314546, COSV63315451; called by muse, mutect2, varscan2
- OR14A16 | c.770T>A p.L257Q | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV62926672; called by muse, mutect2, varscan2
- OR1S2 | c.562C>A p.P188T | Missense Mutation (SNP) | VAF 36/163 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); catalogued as COSV56919381; called by muse, varscan2
- OR2A2 | c.859C>A p.L287M | Missense Mutation (SNP) | VAF 38/218 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.632); catalogued as COSV101286677, COSV68871650; called by muse, mutect2
- OR2F2 | c.62G>A p.W21* | Nonsense Mutation (SNP) | VAF 36/233 reads (15%) | catalogued as COSV101283825; called by muse, mutect2, varscan2
- OR2G2 | c.284T>A p.I95N | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV60740587; called by muse, mutect2, varscan2
- OR2L13 | c.724A>T p.T242S | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (1); PolyPhen possibly damaging (0.469); catalogued as COSV63547393, COSV63552924; called by muse, mutect2
- OR2M2 | c.434C>A p.A145D | Missense Mutation (SNP) | VAF 41/305 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV62898379; called by muse, mutect2, varscan2
- OR2T12 | c.229C>A p.P77T | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58777503; called by muse, varscan2
- OR2T12 | c.76T>C p.F26L | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.109); catalogued as rs759150557, COSV58777512; called by muse, varscan2
- OR2W3 | c.716G>T p.G239V | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as rs1448023356, COSV64456891; called by muse, mutect2, varscan2
- OR2Z1 | c.814A>T p.N272Y | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV100136458; called by muse, mutect2, varscan2
- OR4A47 | c.250T>A p.F84I | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.049); catalogued as COSV71444960; called by muse, mutect2, varscan2
- OR4C13 | c.755G>T p.C252F | Missense Mutation (SNP) | VAF 21/178 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV73648752; called by muse, mutect2, varscan2
- OR4C6 | c.319G>T p.G107C | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV58604104; called by muse, mutect2, varscan2
- OR4D6 | c.874C>A p.Q292K | Missense Mutation (SNP) | VAF 38/194 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV55659798; called by muse, mutect2, varscan2
- OR4K17 | c.906G>T p.W302C | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100210695; called by muse, mutect2, varscan2
- OR4L1 | c.272C>A p.T91N | Missense Mutation (SNP) | VAF 44/189 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV59849778; called by muse, mutect2, varscan2
- OR51A7 | c.933del p.R312Dfs*7 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | catalogued as COSV63788256; called by mutect2, pindel
- OR51G1 | c.176G>T p.G59V | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV58969219; called by muse, mutect2, varscan2
- OR51V1 | c.204G>A p.M68I | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as COSV58315140; called by muse, mutect2
- OR52J3 | c.820C>A p.H274N | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.381); catalogued as COSV66746941; called by muse, mutect2, varscan2
- OR52N5 | c.560A>T p.Y187F | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV57698889, COSV57699156; called by muse, mutect2, varscan2
- OR52N5 | c.113C>A p.P38Q | Missense Mutation (SNP) | VAF 19/189 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV100399722; called by muse, mutect2, varscan2
- OR5AK2 | c.208G>T p.D70Y | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs779663462, COSV100476060, COSV58805027; called by muse, mutect2, varscan2
- OR5J2 | c.485G>T p.S162I | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.942); catalogued as COSV56621284, COSV56623849; called by muse, mutect2, varscan2
- OR5K3 | c.440G>C p.G147A | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.107); catalogued as COSV67349600, COSV67349718; called by muse, mutect2, varscan2
- OR5M10 | c.460C>A p.L154I | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.291); catalogued as COSV101595900; called by muse, mutect2, varscan2
- OR6F1 | c.878G>T p.R293L | Missense Mutation (SNP) | VAF 41/163 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.195); catalogued as COSV57467846; called by muse, mutect2, varscan2
- OR6K6 | c.7C>T p.Q3* | Nonsense Mutation (SNP) | VAF 9/102 reads (9%) | catalogued as COSV100933753; called by muse, mutect2
- OR8H3 | c.422G>T p.C141F | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs558627864, COSV57908991; called by muse, mutect2, varscan2
- OVCH1 | c.1971C>A p.N657K | Missense Mutation (SNP) | VAF 9/197 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as COSV100548782; called by muse, mutect2
- OVCH1 | c.427C>A p.L143M | Missense Mutation (SNP) | VAF 38/339 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58962954; called by muse, mutect2, varscan2
- PAPOLA | c.1966C>T p.H656Y | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.068); catalogued as rs567161516, COSV99354357; called by muse, mutect2, varscan2
- PCDH11X | c.2791G>T p.D931Y | Missense Mutation (SNP) | VAF 48/246 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV53459120, COSV53466685; called by muse, mutect2, varscan2
- PCDH17 | c.3004G>T p.G1002* | Nonsense Mutation (SNP) | VAF 5/62 reads (8%) | catalogued as COSV100931740, COSV100932024; called by muse, mutect2
- PCDH19 | c.3029C>A p.P1010H (on ENST00000373034 / NM_001184880.2; = p.P962H on NM_020766.3) | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.095); catalogued as COSV55263053; called by muse, mutect2, varscan2
- PCDH7 | c.1496G>A p.R499Q | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as COSV62338937; called by muse, mutect2, varscan2
- PCDHA12 | c.1160G>T p.C387F | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100249631, COSV56502090; called by muse, mutect2
- PCDHA6 | c.1870G>A p.V624M | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV65343443; called by muse, mutect2, varscan2
- PCDHB12 | c.2153G>T p.R718M | Missense Mutation (SNP) | VAF 29/210 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV53399345; called by muse, mutect2, varscan2
- PCDHB15 | c.1856C>A p.A619E | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as rs17844634, COSV50931745, COSV51003525; called by muse, mutect2, varscan2
- PCDHB3 | c.1061G>C p.S354T | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.233); catalogued as COSV50574077; called by muse, mutect2, varscan2
- PCDHB3 | c.1333A>C p.N445H | Missense Mutation (SNP) | VAF 28/189 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50574139; called by muse, mutect2, varscan2
- PCDHB5 | c.1333G>T p.D445Y | Missense Mutation (SNP) | VAF 33/244 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50651838; called by muse, mutect2, varscan2
- PCDHGA1 | c.139A>T p.N47Y | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.896); catalogued as COSV65296503; called by muse, mutect2, varscan2
- PCDHGA4 | c.1039G>A p.D347N | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.041); catalogued as COSV53949331; called by mutect2, varscan2
- PCLO | c.9849G>T p.Q3283H | Missense Mutation (SNP) | VAF 28/216 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61635601; called by muse, mutect2, varscan2
- PDCD1LG2 | c.65C>A p.T22K | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as COSV67204623; called by muse, mutect2, varscan2
- PDE4D | c.1858G>T p.D620Y (on ENST00000340635 / NM_001104631.2; = p.D484Y on NM_006203.4) | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100401909; called by muse, mutect2, varscan2
- PDHA2 | c.83C>A p.S28Y | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54779268, COSV54782146; called by muse, mutect2, varscan2
- PGM5 | c.809A>T p.N270I | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67163821; called by muse, mutect2, varscan2
- PHF21B | c.721C>T p.Q241* | Nonsense Mutation (SNP) | VAF 27/156 reads (17%) | catalogued as COSV57558389; called by muse, mutect2, varscan2
- PHLDB1 | c.2642A>G p.Q881R | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV61878439; called by muse, mutect2
- PHLDB2 | c.529C>A p.L177M | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV67311229; called by muse, mutect2, varscan2
- PHOSPHO2 | c.539G>T p.G180V | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99775918; called by muse, mutect2, varscan2
- PIAS1 | c.76G>T p.A26S | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as rs201183628, COSV99986868; called by muse, mutect2, varscan2
- PITX1 | c.571C>A p.P191T | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV54761980; called by muse, mutect2, varscan2
- PIWIL1 | c.1566G>C p.M522I | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV55346817; called by muse, mutect2, varscan2
- PKHD1 | c.2704C>A p.Q902K | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV100583569, COSV100585157; called by muse, mutect2, varscan2
- PKHD1 | c.2703C>A p.N901K | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.441); catalogued as COSV100583571; called by muse, mutect2, varscan2
- PKLR | c.227T>A p.L76Q | Missense Mutation (SNP) | VAF 52/144 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100712922, COSV100712937, COSV61360636; called by muse, mutect2, varscan2
- PKLR | c.226C>A p.L76M | Missense Mutation (SNP) | VAF 51/142 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100712940; called by muse, mutect2, varscan2
- PKP2 | c.2261G>A p.R754K | Missense Mutation (SNP) | VAF 25/308 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.408); catalogued as COSV50731018; called by muse, mutect2
- PLAU | c.398G>T p.C133F | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV65641369; called by muse, mutect2, varscan2
- PLCE1 | c.1690G>T p.G564C | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV53350796; called by muse, mutect2, varscan2
- PLCH2 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs887934400, COSV53943026; called by muse, varscan2
- PLCH2 | c.2009A>G p.Y670C | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV53943037; called by muse, mutect2, varscan2
- PLCL1 | c.3253G>T p.E1085* | Nonsense Mutation (SNP) | VAF 5/42 reads (12%) | catalogued as COSV70825180; called by muse, mutect2, varscan2
- PLD1 | c.2969C>T p.T990I | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV60568104; called by muse, mutect2, varscan2
- PLXNA1 | c.287A>T p.Y96F | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV52526174; called by muse, mutect2, varscan2
- PLXNC1 | c.2659G>A p.G887R | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs1414464957, COSV51575436; called by muse, mutect2, varscan2
- PNLIPRP3 | c.443T>A p.I148N | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65048153; called by muse, mutect2, varscan2
- PNPT1 | c.1117G>T p.E373* | Nonsense Mutation (SNP) | VAF 5/71 reads (7%) | catalogued as COSV53177343; called by muse, mutect2
- POLE | c.1718G>T p.R573L | Missense Mutation (SNP) | VAF 10/123 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.094); catalogued as COSV57680358; called by muse, mutect2
- POLQ | c.1611+1G>C p.X537_splice | Splice Site (SNP) | VAF 13/148 reads (9%) | catalogued as COSV51752183; called by muse, mutect2
- POLR3A | c.2728G>A p.A910T | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.017); catalogued as rs1012934044, COSV64931050; called by muse, mutect2, varscan2
- POTEH | c.506G>A p.R169K | Missense Mutation (SNP) | VAF 45/315 reads (14%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.548); catalogued as COSV58882863; called by muse, varscan2
- PPEF2 | c.2191G>C p.G731R | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV54422512; called by muse, mutect2, varscan2
- PPFIA2 | c.2765G>T p.R922L | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV100334184, COSV61037503; called by muse, mutect2, varscan2
- PPP1R3A | c.2843C>A p.T948K | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.145); catalogued as COSV52877557, COSV99493253; called by muse, mutect2
- PRAMEF1 | c.140G>T p.R47I | Missense Mutation (SNP) | VAF 27/212 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60009356; called by muse, mutect2, varscan2
- PRKD1 | c.2539G>T p.D847Y | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59558319; called by muse, mutect2, varscan2
- PRKG1 | c.1322G>T p.R441I | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV64770686; called by muse, mutect2, varscan2
- PROM1 | c.1207C>A p.Q403K | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.085); catalogued as COSV71699443; called by muse, mutect2, varscan2
- PRRX1 | c.548C>A p.P183H | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV53413814; called by muse, mutect2, varscan2
- PTK7 | c.1285G>T p.G429C | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57848680; called by muse, mutect2, varscan2
- PTPN23 | c.4105C>A p.R1369S | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.158); catalogued as COSV55544624, COSV55544658; called by muse, mutect2, varscan2
- PTPRD | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as rs745977244, COSV61930536; called by muse, mutect2, varscan2
- PTPRF | c.3524G>C p.R1175P | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100741000, COSV63446499; called by muse, mutect2, varscan2
- PXDNL | c.1132G>T p.A378S | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.029); catalogued as COSV62487475; called by muse, mutect2
- RAB9B | c.526G>C p.E176Q | Missense Mutation (SNP) | VAF 13/168 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.261); catalogued as COSV54587585; called by muse, mutect2
- RBBP6 | c.2446G>A p.V816I | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV60505173; called by muse, mutect2, varscan2
- RBFOX2 | c.241A>G p.N81D (on ENST00000438146 / NM_001349995.2; = p.N11D on NM_014309.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.979); catalogued as COSV53264600; called by muse, mutect2, varscan2
- RCC1L | c.1096G>T p.G366W | Missense Mutation (SNP) | VAF 56/156 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782599407, COSV100326933; called by muse, mutect2, varscan2
- RDH16 | c.232G>T p.E78* | Nonsense Mutation (SNP) | VAF 20/119 reads (17%) | catalogued as COSV62458140; called by muse, mutect2, varscan2
- REG1B | c.65-1G>T p.X22_splice | Splice Site (SNP) | VAF 14/147 reads (10%) | catalogued as COSV59305645; called by muse, mutect2, varscan2
- REG3A | c.371G>T p.S124I | Missense Mutation (SNP) | VAF 14/141 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV59409611; called by muse, mutect2
- RELN | c.2681G>A p.C894Y | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV59002606; called by muse, mutect2, varscan2
- RGS1 | c.54C>A p.F18L | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs1334107111, COSV66505354; called by muse, mutect2, varscan2
- RIMS4 | c.105C>A p.S35R | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.017); catalogued as COSV65719721; called by muse, mutect2, varscan2
- RIPOR2 | c.1608T>A p.D536E | Missense Mutation (SNP) | VAF 79/163 reads (48%) | SIFT tolerated (0.82); PolyPhen benign (0.047); catalogued as COSV52422032; called by muse, mutect2, varscan2
- ROR2 | c.1486G>T p.A496S | Missense Mutation (SNP) | VAF 88/315 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0.057); catalogued as COSV65219176; called by muse, mutect2, varscan2
- RPL14 | c.28G>T p.G10C | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV59083020; called by muse, mutect2, varscan2
- RTBDN | c.204G>T p.E68D (on ENST00000393233 / NM_001270444.1; = p.E100D on NM_031429.2) | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.607); catalogued as COSV59806343; called by muse, mutect2
- RYR2 | c.14658C>T p.T4886= | Splice Region (SNP) | VAF 18/142 reads (13%) | catalogued as COSV63686064; called by muse, varscan2
- RYR2 | c.14698A>G p.T4900A | Missense Mutation (SNP) | VAF 20/198 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV63686072; called by muse, varscan2
- SACS | c.8167G>T p.V2723F | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV101207511; called by muse, mutect2, varscan2
- SBSPON | c.377C>A p.T126N | Missense Mutation (SNP) | VAF 65/248 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.154); catalogued as COSV52075980; called by muse, mutect2, varscan2
- SCN1A | c.3235G>C p.V1079L (on ENST00000303395 / NM_001202435.3; = p.V1068L on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV57670349; called by muse, mutect2
- SCRN1 | c.701A>T p.D234V | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV54130840; called by muse, mutect2, varscan2
- SDS | c.298A>C p.K100Q | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0.014); catalogued as COSV57453531; called by muse, mutect2, varscan2
- SEC14L5 | c.1376G>C p.G459A | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV52038509; called by muse, mutect2
- SEC61A2 | c.377G>T p.G126V | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as COSV53650587; called by muse, mutect2
- SENP6 | c.2928G>T p.M976I | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as COSV64187431; called by muse, mutect2, varscan2
- SEPTIN4 | c.354C>A p.S118R | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.009); catalogued as COSV58727889; called by muse, mutect2, varscan2
- SEPTIN5 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 80/169 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63530623; called by muse, mutect2, varscan2
- SERPINA12 | c.757G>T p.D253Y | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV57943690; called by muse, mutect2, varscan2
- SERPINB12 | c.356A>T p.Y119F | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.545); catalogued as COSV54033211; called by muse, mutect2, varscan2
- SERPINI2 | c.1142-1G>A p.X381_splice | Splice Site (SNP) | VAF 9/25 reads (36%) | catalogued as rs747834843, COSV52987598, COSV99248049; called by muse, mutect2, varscan2
- SESTD1 | c.1150C>A p.H384N | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as COSV58930657; called by muse, mutect2, varscan2
- SETBP1 | c.2497A>T p.R833* | Nonsense Mutation (SNP) | VAF 5/68 reads (7%) | catalogued as COSV56322198; called by muse, mutect2
- SF3B2 | c.704C>T p.T235I | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.044); catalogued as COSV59428205; called by muse, mutect2, varscan2
- SGSM1 | c.2348C>T p.S783L (on ENST00000400359 / NM_001039948.4; = p.S722L on NM_133454.3) | Missense Mutation (SNP) | VAF 15/194 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as rs750258760, COSV63082433; called by muse, mutect2
- SGSM3 | c.541G>T p.V181L | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as rs776452412, COSV50652236; called by muse, mutect2
- SH3TC2 | c.3749A>T p.Q1250L | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV60463315; called by muse, mutect2
- SH3TC2 | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs142488510, COSV60463331; called by muse, mutect2, varscan2
- SHROOM3 | c.2605G>A p.G869R | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs1260796052, COSV56029376; called by muse, mutect2, varscan2
- SIGLEC10 | c.1114G>C p.E372Q | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV59481789; called by muse, mutect2, varscan2
- SLAMF8 | c.763C>T p.H255Y | Missense Mutation (SNP) | VAF 54/220 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV56988436; called by muse, mutect2, varscan2
- SLAMF9 | c.665-2A>T p.X222_splice | Splice Site (SNP) | VAF 14/61 reads (23%) | catalogued as COSV100928147; called by muse, mutect2
- SLC12A5 | c.1793C>T p.A598V (on ENST00000454036 / NM_001134771.2; = p.A575V on NM_020708.5) | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV54793849; called by muse, mutect2, varscan2
- SLC12A7 | c.207G>T p.M69I | Missense Mutation (SNP) | VAF 6/103 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV53757323; called by muse, mutect2
- SLC22A11 | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.377); catalogued as rs1390117057, COSV57253201; called by muse, mutect2, varscan2
- SLC22A25 | c.58C>A p.Q20K | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100123697; called by muse, mutect2, varscan2
- SLC26A3 | c.539C>A p.A180E | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.474); catalogued as COSV60640343; called by muse, mutect2, varscan2
- SLC26A7 | c.542C>A p.A181E | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV52593520; called by muse, mutect2
- SLC26A7 | c.1161C>A p.C387* | Nonsense Mutation (SNP) | VAF 71/195 reads (36%) | catalogued as COSV52590218, COSV52593540; called by muse, mutect2, varscan2
- SLC36A1 | c.883G>C p.G295R | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54653838; called by muse, mutect2, varscan2
- SLC4A1 | c.535A>C p.T179P | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV99293429; called by muse, mutect2, varscan2
- SLC5A4 | c.1945G>T p.A649S | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as COSV56670484; called by mutect2, varscan2
- SLC9A1 | c.2302G>T p.E768* | Nonsense Mutation (SNP) | VAF 22/115 reads (19%) | catalogued as COSV99849789; called by muse, mutect2, varscan2
- SLITRK5 | c.923C>A p.T308N | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.677); catalogued as COSV61522964; called by muse, mutect2
- SMAP2 | c.809C>T p.S270L | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV65532334; called by muse, mutect2, varscan2
- SMARCAD1 | c.802A>G p.K268E | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs759300612; called by muse, mutect2
- SMURF1 | c.1287G>T p.M429I | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as COSV63157533; called by muse, mutect2, varscan2
- SND1 | c.498G>T p.E166D | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT tolerated (0.65); PolyPhen benign (0.065); catalogued as COSV100690619; called by muse, mutect2
- SND1 | c.499G>T p.G167W | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV100690621; called by muse, mutect2
- SNIP1 | c.519G>T p.Q173H | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.135); catalogued as COSV56166565; called by muse, mutect2, varscan2
- SNTG1 | c.603G>C p.K201N | Missense Mutation (SNP) | VAF 65/224 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.966); catalogued as COSV52444200; called by muse, varscan2
- SNX1 | c.160-1G>T p.X54_splice | Splice Site (SNP) | VAF 9/67 reads (13%) | catalogued as COSV56038318; called by muse, mutect2, varscan2
- SNX25 | c.200T>C p.L67S | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1396737509, COSV53014522; called by muse, mutect2, varscan2
- SOWAHC | c.1112G>T p.R371M | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV61780303; called by muse, mutect2, varscan2
- SOX6 | c.2390G>T p.G797V (on ENST00000528429 / NM_001145819.2; = p.G770V on NM_017508.3) | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV57046104; called by muse, mutect2, varscan2
- SP110 | c.1049-1G>T p.X350_splice | Splice Site (SNP) | VAF 16/108 reads (15%) | catalogued as COSV51251036; called by muse, mutect2, varscan2
- SPANXN2 | c.84G>T p.Q28H | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.988); catalogued as COSV65128423; called by muse, mutect2, varscan2
- SPATA31A3 | c.493C>A p.L165M | Missense Mutation (SNP) | VAF 65/616 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs368133001; called by muse, mutect2, varscan2
- SPEF2 | c.1507G>T p.D503Y | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56796933; called by muse, mutect2
- SPHKAP | c.3194C>A p.P1065H | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as COSV60879255, COSV60889955; called by muse, mutect2, varscan2
- SPINK13 | c.204C>G p.F68L | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as COSV101268305; called by muse, mutect2, varscan2
- SPTA1 | c.2332C>A p.L778M | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63751430, COSV63753232; called by muse, mutect2, varscan2
- SPTAN1 | c.4076G>T p.R1359L | Missense Mutation (SNP) | VAF 66/246 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.107); catalogued as COSV63987184; called by muse, mutect2, varscan2
- SPTB | c.2109G>T p.M703I | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.101); catalogued as COSV67631857; called by muse, mutect2, varscan2
- SRGAP1 | c.2302G>T p.A768S | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.199); catalogued as COSV61898100; called by muse, varscan2
- SSTR5 | c.58G>T p.A20S | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.69); PolyPhen benign (0.018); catalogued as COSV99559768; called by muse, mutect2, varscan2
- ST8SIA3 | c.148C>A p.P50T | Missense Mutation (SNP) | VAF 13/105 reads (12%) | PolyPhen probably damaging (0.994); catalogued as COSV60654183; called by muse, mutect2, varscan2
- SUGP1 | c.193C>T p.P65S | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs796157071, COSV53235416; called by muse, mutect2, varscan2
- SV2C | c.599G>T p.G200V | Missense Mutation (SNP) | VAF 41/204 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV59220194; called by muse, mutect2, varscan2
- SYMPK | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.476); catalogued as COSV55571836, COSV55575022; called by muse, mutect2, varscan2
- SYNE1 | c.24911C>A p.P8304H (on ENST00000367255 / NM_182961.4; = p.P8233H on NM_033071.3) | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV54983861; called by muse, mutect2, varscan2
- SYNPO2 | c.2710A>T p.T904S | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.508); catalogued as COSV61110956; called by muse, mutect2, varscan2
- SYT10 | c.908C>A p.P303H | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV57340633; called by muse, mutect2, varscan2
- SYT14 | c.542C>A p.P181H | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.258); catalogued as COSV55054401; called by muse, mutect2, varscan2
- SYT9 | c.1433G>T p.R478L | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59618484; called by muse, mutect2, varscan2
- TAF1 | c.737A>C p.H246P (on ENST00000373790 / NM_138923.4; = p.H267P on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV52113606; called by muse, mutect2, varscan2
- TAGLN3 | c.529C>A p.Q177K | Missense Mutation (SNP) | VAF 9/131 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV56327943, COSV56329244; called by muse, mutect2
- TASOR2 | c.2010G>T p.E670D | Missense Mutation (SNP) | VAF 27/219 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV60167514; called by muse, mutect2, varscan2
- TASOR2 | c.5441G>T p.G1814V | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60167519; called by muse, mutect2, varscan2
- TATDN1 | c.28G>T p.G10C | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52679520; called by muse, mutect2, varscan2
- TBC1D9B | c.1567G>T p.G523W | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766343754, COSV100783565; called by mutect2, varscan2
- TBL1X | c.1117C>A p.P373T | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV54280241; called by muse, mutect2, varscan2
- TCF23 | c.364G>T p.A122S | Missense Mutation (SNP) | VAF 71/176 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV99940358; called by muse, mutect2, varscan2
- TCHH | c.4998C>A p.D1666E | Missense Mutation (SNP) | VAF 88/188 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); catalogued as COSV64274848; called by muse, mutect2, varscan2
- TCTEX1D1 | c.440G>T p.R147I | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51075707, COSV51076159; called by muse, mutect2, varscan2
- TENM1 | c.7411C>A p.P2471T | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as COSV64432070; called by muse, mutect2, varscan2
- TENT5D | c.157G>A p.G53R | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100383047, COSV57636713; called by muse, mutect2, varscan2
- TF | c.1424G>C p.R475T | Missense Mutation (SNP) | VAF 117/311 reads (38%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.647); catalogued as COSV53920384; called by muse, mutect2, varscan2
- TFDP3 | c.487C>A p.R163S | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV59536346, COSV59536950; called by muse, mutect2, varscan2
- TG | c.6461G>C p.C2154S | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as CM063193, COSV55076438; called by muse, mutect2, varscan2
- TGFB2 | c.896G>T p.R299L | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as CM1210057, COSV65108222, COSV65109328; called by muse, mutect2, varscan2
- TGFBRAP1 | c.674G>T p.G225V | Missense Mutation (SNP) | VAF 37/286 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.844); catalogued as COSV99305223; called by muse, mutect2, varscan2
- THG1L | c.652G>C p.E218Q | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV51452907; called by muse, mutect2
- THRAP3 | c.1945A>G p.T649A | Missense Mutation (SNP) | VAF 36/299 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV63567828; called by muse, mutect2, varscan2
- TLL2 | c.1349A>G p.N450S | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.061); catalogued as rs1205876498, COSV63572492; called by muse, mutect2, varscan2
- TM4SF1 | c.535A>T p.I179F | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.543); catalogued as rs774586987, COSV59524917; called by muse, mutect2
- TM6SF2 | c.886C>T p.P296S | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.752); catalogued as COSV52269513; called by muse, mutect2, varscan2
- TMEM130 | c.1204G>A p.G402R (on ENST00000416379 / NM_001134450.2; = p.G390R on NM_152913.3) | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV59559220; called by muse, mutect2, varscan2
- TMEM82 | c.602C>A p.P201H | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99606677; called by muse, mutect2
- TMEM87B | c.1054G>T p.V352F | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs761998812, COSV51715298; called by muse, mutect2, varscan2
- TMPRSS4 | c.157+1G>T p.X53_splice | Splice Site (SNP) | VAF 11/85 reads (13%) | catalogued as COSV71109177; called by muse, mutect2, varscan2
- TNFSF8 | c.409G>T p.G137C | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56342525; called by muse, mutect2
- TNN | c.2569C>A p.P857T | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53426390; called by muse, mutect2, varscan2
- TNN | c.2857G>T p.V953L | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0.403); catalogued as rs372170240, COSV53426400; called by muse, mutect2, varscan2
- TNNT3 | c.187G>T p.E63* (on ENST00000397301 / NM_001367846.1; = p.E52* on NM_006757.4) | Nonsense Mutation (SNP) | VAF 17/126 reads (13%) | catalogued as COSV99548560; called by muse, mutect2, varscan2
- TNR | c.3661C>T p.Q1221* | Nonsense Mutation (SNP) | VAF 16/85 reads (19%) | catalogued as COSV54885890; called by muse, mutect2, varscan2
- TPP2 | c.2900G>T p.C967F | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.271); catalogued as COSV65752705; called by muse, mutect2
- TRAF3IP3 | c.106C>A p.R36S | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs981440427, COSV50550785, COSV50553080; called by muse, mutect2, varscan2
- TRIM56 | c.1663G>T p.V555L | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.917); catalogued as COSV100047449; called by muse, mutect2, varscan2
- TRIM63 | c.160G>T p.A54S | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.173); catalogued as COSV65328475; called by muse, mutect2
- TRIM9 | c.2065G>T p.V689L | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV53612814; called by muse, mutect2, varscan2
- TRIML1 | c.379C>A p.L127I | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as COSV60194308; called by muse, mutect2, varscan2
- TSHZ3 | c.2848C>A p.L950M | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53667643; called by muse, mutect2, varscan2
- TSHZ3 | c.1628G>C p.S543T | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.931); catalogued as COSV53671825; called by muse, mutect2
- TSPAN14 | c.205G>T p.G69C | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100540312; called by muse, mutect2, varscan2
- TSPAN16 | c.228G>T p.W76C | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.078); catalogued as COSV100368384, COSV57443010; called by mutect2, varscan2
- TTN | c.29354C>T p.S9785F (on ENST00000591111; = p.S8858F on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/111 reads (10%) | PolyPhen probably damaging (0.974); catalogued as COSV59938940; called by muse, mutect2, varscan2
- TUBA1A | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as rs1565627084, CM125541, COSV55497840; called by muse, mutect2, varscan2
- TUBA4A | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV50278235; called by muse, mutect2, varscan2
- TYR | c.963C>A p.C321* | Nonsense Mutation (SNP) | VAF 20/164 reads (12%) | catalogued as COSV54475695; called by muse, mutect2, varscan2
- UBE2O | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 28/270 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs764459575, COSV60063234; called by muse, mutect2, varscan2
- UBE2R2 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.023); catalogued as COSV54289631; called by muse, mutect2, varscan2
- UGT2B4 | c.1420A>G p.K474E | Missense Mutation (SNP) | VAF 26/203 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV59317236; called by muse, varscan2
- UGT2B4 | c.1386C>A p.F462L | Missense Mutation (SNP) | VAF 24/196 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs745780826, COSV59317246, COSV59320314; called by muse, varscan2
- UNC119 | c.610+7G>T | Splice Region (SNP) | VAF 13/64 reads (20%) | catalogued as COSV99971737; called by muse, mutect2, varscan2
- UNC79 | c.3591G>T p.R1197S (on ENST00000393151 / NM_001346218.2; = p.R1020S on NM_020818.5) | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.254); catalogued as COSV56388291; called by muse, mutect2
- URGCP | c.217C>T p.L73F (on ENST00000453200 / NM_001077663.3; = p.L64F on NM_017920.4) | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.511); catalogued as COSV56247831; called by muse, mutect2
- URI1 | c.562T>G p.S188A | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.05); catalogued as COSV100369063; called by muse, mutect2, varscan2
- USF3 | c.3145C>T p.Q1049* | Nonsense Mutation (SNP) | VAF 15/95 reads (16%) | catalogued as COSV57072780; called by muse, mutect2, varscan2
- USF3 | c.1685C>T p.P562L | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV57072788; called by muse, mutect2, varscan2
- USH2A | c.15227G>T p.R5076I | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56331616, COSV56370180; called by muse, mutect2, varscan2
- USH2A | c.9424G>C p.G3142R | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs397518048, CM073413, COSV100237450, COSV56335394; called by muse, mutect2, varscan2
- USH2A | c.2438G>A p.G813E | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1330954314, COSV100240138, COSV56370519; called by muse, mutect2, varscan2
- USP24 | c.2179G>T p.G727C | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.436); catalogued as COSV99600110; called by muse, mutect2, varscan2
- USP29 | c.629C>A p.P210Q | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0.045); catalogued as COSV54142695; called by muse, mutect2
- USP31 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV54852273, COSV54854101; called by muse, mutect2, varscan2
- USP40 | c.674G>A p.R225K | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as COSV52480990; called by muse, mutect2, varscan2
- USPL1 | c.1184G>T p.G395V | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54999984; called by muse, mutect2, varscan2
- UTP25 | c.2090A>G p.Y697C | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143737076; called by muse, mutect2, varscan2
- UVRAG | c.944C>T p.T315I | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV62104326, COSV62105871; called by muse, mutect2, varscan2
- VCAN | c.7951C>A p.H2651N | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.057); catalogued as COSV54105247; called by muse, mutect2, varscan2
- VCAN | c.8818G>C p.V2940L | Missense Mutation (SNP) | VAF 80/317 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54105269; called by muse, mutect2
- VCAN | c.9592C>A p.R3198S | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54099409, COSV54105278; called by muse, mutect2, varscan2
- VCP | c.787G>T p.G263* | Nonsense Mutation (SNP) | VAF 20/295 reads (7%) | catalogued as COSV62720562; called by muse, mutect2
- VIL1 | c.1273G>T p.D425Y | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50288180; called by muse, mutect2, varscan2
- VIP | c.151C>G p.Q51E | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV100923942, COSV65889334; called by muse, mutect2, varscan2
- WDFY3 | c.8843C>T p.P2948L | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55701149; called by muse, mutect2, varscan2
- WDR41 | c.436G>C p.D146H | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.441); catalogued as COSV56998839; called by muse, mutect2
- XIRP2 | c.2470C>T p.H824Y (on ENST00000628543; = p.H999Y on NM_152381.6) | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54700953; called by muse, mutect2, varscan2
- ZBTB16 | c.710G>T p.G237V | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.026); catalogued as COSV60093163, COSV60100543; called by muse, mutect2, varscan2
- ZBTB18 | c.536A>T p.E179V | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.981); catalogued as COSV62397010; called by muse, mutect2, varscan2
- ZC3H12C | c.790G>T p.V264L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV53708896; called by muse, mutect2, varscan2
- ZC3H12C | c.2369G>C p.R790P | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.608); catalogued as COSV53708908, COSV53710365; called by muse, mutect2, varscan2
- ZC3H7B | c.1018G>A p.D340N | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.23); catalogued as rs1180348998; called by mutect2, varscan2
- ZEB2 | c.2154C>A p.N718K | Missense Mutation (SNP) | VAF 43/313 reads (14%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as COSV57956962; called by muse, mutect2, varscan2
- ZEB2 | c.1567A>G p.K523E | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57956972, COSV57957267; called by muse, mutect2, varscan2
- ZEB2 | c.144G>C p.E48D | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.899); catalogued as COSV57952810, COSV57956984; called by muse, mutect2, varscan2
- ZFHX4 | c.349A>T p.S117C | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV50808738; called by muse, mutect2
- ZFP57 | c.903G>T p.Q301H | Missense Mutation (SNP) | VAF 37/207 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100971876, COSV65306160; called by muse, mutect2, varscan2
- ZIM3 | c.1417T>C p.*473Qext*24 | Nonstop Mutation (SNP) | VAF 8/63 reads (13%) | catalogued as rs1239219077, COSV54142710; called by muse, mutect2, varscan2
- ZIM3 | c.148G>A p.G50R | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1210324853, COSV54142721; called by muse, mutect2, varscan2
- ZNF154 | c.1223C>A p.T408N | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); catalogued as rs1222248309, COSV101377445; called by muse, mutect2
- ZNF208 | c.3036G>T p.W1012C | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.862); catalogued as rs1005800175; called by muse, mutect2
- ZNF268 | c.277G>T p.E93* | Nonsense Mutation (SNP) | VAF 15/62 reads (24%) | catalogued as COSV57212924; called by muse, mutect2, varscan2
- ZNF273 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 52/234 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs148564376; called by muse, mutect2, varscan2
- ZNF385D | c.677C>G p.T226S | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.82); PolyPhen benign (0.117); catalogued as COSV55756220; called by muse, mutect2
- ZNF423 | c.2684G>T p.G895V (on ENST00000563137 / NM_001379286.1; = p.G887V on NM_015069.4) | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.963); catalogued as COSV52186628, COSV52189049; called by muse, mutect2, varscan2
- ZNF423 | c.1939C>T p.L647F (on ENST00000563137 / NM_001379286.1; = p.L639F on NM_015069.4) | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.811); catalogued as rs1186676819, COSV52189073; called by muse, mutect2, varscan2
- ZNF438 | c.1453A>C p.N485H | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as COSV59195244; called by muse, mutect2, varscan2
- ZNF442 | c.1670C>G p.T557S | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54421547; called by muse, mutect2, varscan2
- ZNF479 | c.884G>T p.R295I | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.58); catalogued as COSV100482705, COSV58635981, COSV58638464; called by muse, mutect2, varscan2
- ZNF521 | c.3055G>T p.G1019C | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64127037; called by muse, mutect2, varscan2
- ZNF521 | c.2037G>T p.L679F | Missense Mutation (SNP) | VAF 26/187 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.928); catalogued as COSV64127042; called by muse, varscan2
- ZNF560 | c.1489T>A p.F497I | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56867904; called by muse, mutect2
- ZNF677 | c.16-1G>T p.X6_splice | Splice Site (SNP) | VAF 7/60 reads (12%) | catalogued as COSV100448019; called by muse, mutect2, varscan2
- ZNF680 | c.75G>T p.E25D | Missense Mutation (SNP) | VAF 22/370 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV59014432, COSV59015812; called by muse, mutect2
- ZNF699 | c.782G>T p.S261I | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV58025666; called by muse, mutect2, varscan2
- ZNF80 | c.719C>A p.T240N | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); catalogued as COSV57360783; called by muse, mutect2, varscan2
- ZNF804A | c.2124G>T p.M708I | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs770266673, COSV100168591; called by muse, mutect2, varscan2
- ZNF804B | c.805G>T p.A269S | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.314); catalogued as COSV60828438, COSV60847716; called by muse, mutect2
- ZNF91 | c.635G>T p.C212F | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as COSV100322955, COSV56081004, COSV56095107; called by mutect2, varscan2
- ZPLD1 | c.1018G>T p.A340S (on ENST00000466937 / NM_001329788.1; = p.A356S on NM_175056.2) | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.065); catalogued as rs1399425816, COSV60353588; called by muse, mutect2, varscan2
- ZSWIM2 | c.944A>T p.Q315L | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV54575533; called by muse, mutect2, varscan2
- ZZZ3 | c.646G>T p.D216Y | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.347); catalogued as COSV66232772; called by muse, mutect2, varscan2
- AADAC | c.562G>C p.D188H | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- AC013489.1 | c.1238C>G p.S413C | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- AIMP1 | c.526G>A p.V176M | Missense Mutation (SNP) | VAF 16/306 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- ANKEF1 | c.1890dup p.A631Cfs*6 | Frame Shift Ins (INS) | VAF 60/180 reads (33%) | called by mutect2, pindel, varscan2
- CASP14 | c.579del p.D193Efs*14 | Frame Shift Del (DEL) | VAF 10/82 reads (12%) | called by mutect2, varscan2
- CDS2 | c.797del p.G266Afs*15 | Frame Shift Del (DEL) | VAF 17/82 reads (21%) | called by mutect2, pindel, varscan2
- CLU | c.80C>G p.S27* | Nonsense Mutation (SNP) | VAF 8/95 reads (8%) | called by muse, mutect2
- CRYBA2 | c.542del p.G181Afs*27 | Frame Shift Del (DEL) | VAF 9/73 reads (12%) | called by mutect2, pindel, varscan2
- DGKB | c.266dup p.N89Kfs*7 | Frame Shift Ins (INS) | VAF 9/22 reads (41%) | called by mutect2, pindel, varscan2
- DIO2 | c.100C>A p.L34I | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.27); called by muse, mutect2
- DNAI4 | c.1161G>T p.E387D | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DST | c.2490del p.K831Sfs*13 (on ENST00000361203 / NM_001374722.1; = p.K505Sfs*13 on NM_001723.6) | Frame Shift Del (DEL) | VAF 13/55 reads (24%) | called by mutect2, pindel, varscan2
- ELAVL4 | c.420del p.T142Pfs*2 | Frame Shift Del (DEL) | VAF 19/142 reads (13%) | called by mutect2, pindel, varscan2
- EPHA8 | c.398dup p.A135Gfs*68 | Frame Shift Ins (INS) | VAF 6/58 reads (10%) | called by mutect2, varscan2
- FLI1 | c.1215dup p.S406Ifs*36 | Frame Shift Ins (INS) | VAF 7/42 reads (17%) | called by mutect2, pindel
- FMNL2 | c.301C>G p.Q101E | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.83); called by muse, mutect2
- FOXD4L5 | c.378C>A p.H126Q | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.089); called by mutect2, varscan2
- GRB10 | c.1171A>T p.M391L (on ENST00000398812; = p.M345L on NM_001001549.3) | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.007); called by muse, mutect2
- GRID2 | c.2632del p.H878Ifs*4 | Frame Shift Del (DEL) | VAF 24/144 reads (17%) | called by mutect2, pindel, varscan2
- IGHV1OR15-9 | c.85G>C p.E29Q | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- IGHV3-38 | c.220A>T p.S74C | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); called by muse, mutect2
- ILDR2 | c.764del p.G255Afs*19 | Frame Shift Del (DEL) | VAF 10/62 reads (16%) | called by mutect2, pindel, varscan2
- IMPG2 | c.1266del p.S423Qfs*36 | Frame Shift Del (DEL) | VAF 16/123 reads (13%) | called by mutect2, pindel, varscan2
- KLHL5 | c.1810del p.A604Qfs*3 | Frame Shift Del (DEL) | VAF 7/38 reads (18%) | called by mutect2, pindel, varscan2
- MAGEB6B | c.418del p.R140Vfs*39 | Frame Shift Del (DEL) | VAF 17/113 reads (15%) | called by mutect2, pindel, varscan2
- MARCO | c.459dup p.G154Rfs*23 | Frame Shift Ins (INS) | VAF 21/160 reads (13%) | called by mutect2, pindel, varscan2
- MUC17 | c.2793del p.D931Efs*6 | Frame Shift Del (DEL) | VAF 116/753 reads (15%) | called by mutect2, pindel, varscan2
- MYO18B | c.4849C>A p.L1617I | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.16); called by muse, mutect2
- MYO1D | c.1610A>G p.N537S | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.264); called by muse, mutect2
- NCAN | c.1420G>T p.D474Y | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.054); called by mutect2, varscan2
- PCDHGA11 | c.785dup p.L263Afs*4 | Frame Shift Ins (INS) | VAF 21/204 reads (10%) | called by mutect2, pindel, varscan2
- PLA2G4C | c.789del p.G264Vfs*22 | Frame Shift Del (DEL) | VAF 15/47 reads (32%) | called by mutect2, pindel, varscan2
- PLCG2 | c.921_922insT p.A308Cfs*21 | Frame Shift Ins (INS) | VAF 8/55 reads (15%) | called by mutect2, varscan2*
- PLCXD3 | c.834G>T p.Q278H | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- POLR2A | c.2588G>T p.R863L | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- POTEA | c.244G>C p.D82H | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- PRAMEF8 | c.1057C>A p.L353M | Missense Mutation (SNP) | VAF 18/203 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- PRDX6 | c.413del p.G138Vfs*6 | Frame Shift Del (DEL) | VAF 26/275 reads (9%) | called by mutect2, pindel
- RYR2 | c.7490G>T p.R2497L | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SERPINA6 | c.1170del p.F391Sfs*12 | Frame Shift Del (DEL) | VAF 16/108 reads (15%) | called by mutect2, pindel, varscan2
- SFTPD | c.842del p.C281Sfs*25 | Frame Shift Del (DEL) | VAF 14/111 reads (13%) | called by mutect2, pindel, varscan2
- SGCE | c.795T>A p.D265E (on ENST00000647096; = p.D229E on NM_003919.3) | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SH2D5 | c.870C>G p.S290R (on ENST00000444387 / NM_001103161.2; = p.S206R on NM_001103160.2) | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- SPATA17 | c.684del p.S229Lfs*23 | Frame Shift Del (DEL) | VAF 10/55 reads (18%) | called by mutect2, pindel, varscan2
- SPDYE3 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.537); called by muse, mutect2
211 further variants in this file (12 protein-altering or splice-affecting, 175 silent, 24 other) are not listed here.
